Somatic mutation profile of tumor specimen c952715e-35ca-4e18-ad6f-dd4e39 (aliquot c952715e-35ca-4e18-ad6f-dd4e39_D6_1) from CPTAC case 05CO039, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIB.
Specimen c952715e-35ca-4e18-ad6f-dd4e39: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4dedaa99-e81b-4cb9-95cb-7fd733921d96.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 38dbebd9-e1ba-475d-bc18-1e3506 (Blood Derived Normal), aliquot 38dbebd9-e1ba-475d-bc18-1e3506_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc55512-d57b-4062-9068-b47848e5fd01

The open-access MAF lists 1,913 somatic variants for this specimen: 1,306 protein-altering or splice-affecting, 361 silent, 246 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 849, Silent 361, Frame Shift Del 279, Intron 135, Frame Shift Ins 70, 3'UTR 38, Nonsense Mutation 38, RNA 29, Splice Site 27, Splice Region 26, 5'UTR 18, 5'Flank 15.

Variants (750 of 1,913; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 175/467 reads (37%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, varscan2
- AXIN2 | c.1994del p.G665Afs*24 | Frame Shift Del (DEL) | VAF 89/252 reads (35%) | catalogued as rs267606674; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 69/228 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GAA | c.258del p.N87Tfs*55 | Frame Shift Del (DEL) | VAF 146/430 reads (34%) | catalogued as rs761317813; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- GBA | c.1090G>A p.G364R | Missense Mutation (SNP) | VAF 246/820 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs121908305, CM014190, CM900104; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 78/210 reads (37%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PKD1 | c.8311G>A p.E2771K | Missense Mutation (SNP) | VAF 26/842 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518897, CM010386, CX1210805; ClinVar: pathogenic; called by muse, mutect2
- SLCO2A1 | c.830del p.F277Sfs*8 | Frame Shift Del (DEL) | VAF 138/298 reads (46%) | catalogued as rs751192029; ClinVar: pathogenic; called by mutect2, varscan2
- AARD | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 91/284 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100991995; called by muse, mutect2, varscan2
- ABCB10 | c.1501T>C p.Y501H | Missense Mutation (SNP) | VAF 102/441 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs576357405; called by muse, mutect2, varscan2
- ABCB6 | c.1901G>A p.R634H | Missense Mutation (SNP) | VAF 64/213 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759447077, COSV54696551; called by muse, mutect2, varscan2
- ABCB6 | c.1453-2A>G p.X485_splice | Splice Site (SNP) | VAF 71/189 reads (38%) | catalogued as rs375304697; called by muse, mutect2, varscan2
- ABCF1 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 110/261 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.845); catalogued as rs145174924; called by muse, mutect2, varscan2
- ABI2 | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV53695002; called by muse, mutect2
- AC005833.1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious, low confidence (0); catalogued as rs1213430605; called by muse, mutect2, varscan2
- AC013489.1 | c.952C>A p.R318S | Missense Mutation (SNP) | VAF 89/198 reads (45%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.506); catalogued as COSV51550593; called by muse, mutect2, varscan2
- ACVR2A | c.285del p.D96Tfs*54 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs1312707585, COSV54026507; called by mutect2, varscan2
- ADAMTS1 | c.1253C>A p.A418D | Missense Mutation (SNP) | VAF 47/116 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV53170705, COSV99536294; called by muse, mutect2, varscan2
- ADAMTS19 | c.964C>T p.R322* | Nonsense Mutation (SNP) | VAF 39/81 reads (48%) | catalogued as rs1261670879, COSV50731304; called by muse, mutect2, varscan2
- ADAMTSL3 | c.497A>G p.H166R | Missense Mutation (SNP) | VAF 183/424 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV54465804; called by muse, mutect2, varscan2
- ADCY3 | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 196/464 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766455325; called by muse, mutect2, varscan2
- ADCY5 | c.3212C>T p.A1071V | Missense Mutation (SNP) | VAF 160/409 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.984); catalogued as rs1395773373, COSV100567301; called by muse, mutect2, varscan2
- ADCY5 | c.178dup p.A60Gfs*27 | Frame Shift Ins (INS) | VAF 13/39 reads (33%) | catalogued as rs756172692; called by mutect2, varscan2
- ADGRA2 | c.2344C>T p.L782F | Missense Mutation (SNP) | VAF 46/148 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1239984335; called by muse, mutect2, varscan2
- ADGRA3 | c.3661C>T p.R1221* | Nonsense Mutation (SNP) | VAF 128/309 reads (41%) | catalogued as rs1040664017; called by muse, mutect2, varscan2
- ADPRM | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 107/252 reads (42%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs150191988; called by muse, mutect2, varscan2
- ADRA1D | c.580C>T p.R194W | Missense Mutation (SNP) | VAF 136/323 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868511687, COSV65241145; called by muse, mutect2, varscan2
- AFF2 | c.3712C>T p.R1238C | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1263514787, COSV53981655, COSV99664742; called by muse, mutect2
- AFF3 | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 180/405 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV57839667; called by muse, mutect2, varscan2
- AFG1L | c.470G>A p.R157K | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as COSV64555738; called by mutect2, varscan2
- AMER1 | c.1370A>C p.Q457P | Missense Mutation (SNP) | VAF 88/107 reads (82%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs780393025; called by muse, mutect2, varscan2
- AMER3 | c.1637dup p.R547Qfs*64 | Frame Shift Ins (INS) | VAF 34/98 reads (35%) | catalogued as rs893863661; called by pindel, varscan2
- ANK1 | c.4136C>T p.P1379L | Missense Mutation (SNP) | VAF 206/601 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748160803, COSV55890290; called by muse, mutect2, varscan2
- ANKFY1 | c.2737G>A p.A913T (on ENST00000341657 / NM_001330063.2; = p.A914T on NM_016376.5) | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1261557692, COSV100492162; called by muse, mutect2, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 36/96 reads (38%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKRD65 | c.1165dup p.E389Gfs*5 | Frame Shift Ins (INS) | VAF 76/174 reads (44%) | catalogued as rs534554090; called by mutect2, varscan2
- ANKS1A | c.2083C>T p.R695W | Missense Mutation (SNP) | VAF 71/179 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs776379008, COSV64463855; called by muse, varscan2
- ANKS1B | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 39/73 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.367); catalogued as COSV61336899; called by muse, mutect2, varscan2
- ANKS6 | c.581C>T p.A194V | Missense Mutation (SNP) | VAF 291/766 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.892); catalogued as rs754441342; called by muse, mutect2, varscan2
- ANO3 | c.1470G>A p.W490* | Nonsense Mutation (SNP) | VAF 19/25 reads (76%) | catalogued as CM1211482; called by muse, mutect2, varscan2
- ANXA13 | c.107C>A p.A36D | Missense Mutation (SNP) | VAF 56/244 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.29); catalogued as COSV51622879; called by muse, mutect2, varscan2
- AP002495.1 | c.496C>T p.R166* (on ENST00000528511; = p.R97* on NM_001375848.1) | Nonsense Mutation (SNP) | VAF 61/152 reads (40%) | catalogued as rs533329465; called by muse, mutect2
- AP1M2 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs199783174; called by muse, varscan2
- APIP | c.283del p.S95Afs*8 | Frame Shift Del (DEL) | VAF 24/46 reads (52%) | catalogued as rs546686089; called by mutect2, varscan2
- APOA5 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 134/334 reads (40%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); catalogued as rs1343847704; called by muse, mutect2, varscan2
- AQP7 | c.700dup p.R234Pfs*61 | Frame Shift Ins (INS) | VAF 152/372 reads (41%) | catalogued as rs3215969; called by mutect2, varscan2
- AQR | c.1046A>G p.Y349C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.525); catalogued as rs777333533; called by muse, mutect2, varscan2
- ARHGAP11A | c.1567G>T p.G523* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100853391; called by muse, mutect2, varscan2
- ARHGAP31 | c.3881C>T p.S1294L | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs759632773, COSV99956952; called by muse, mutect2, varscan2
- ARHGAP39 | c.2537C>T p.T846M (on ENST00000276826 / NM_001308208.2; = p.T877M on NM_025251.2) | Missense Mutation (SNP) | VAF 102/420 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs199672590; called by muse, mutect2, varscan2
- ARHGEF40 | c.2209del p.A737Pfs*3 | Frame Shift Del (DEL) | VAF 54/164 reads (33%) | catalogued as rs749402223; called by mutect2, pindel, varscan2
- ARID5B | c.1010C>T p.T337M | Missense Mutation (SNP) | VAF 9/205 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1269760932, COSV54414533; called by muse, mutect2
- ARRB1 | c.273del p.E92Rfs*6 | Frame Shift Del (DEL) | VAF 72/220 reads (33%) | catalogued as COSV63574872; called by mutect2, pindel, varscan2
- ARRDC5 | c.193G>A p.E65K (on ENST00000381781; = p.E51K on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 153/390 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.327); catalogued as rs755493046; called by muse, varscan2
- ASAP3 | c.2128C>T p.R710C | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.183); catalogued as rs147016526; called by muse, mutect2, varscan2
- ASB10 | c.548G>A p.R183H (on ENST00000420175 / NM_001142459.2; = p.R168H on NM_080871.4) | Missense Mutation (SNP) | VAF 124/289 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1363117706; called by muse, mutect2, varscan2
- ASPG | c.1256C>T p.A419V | Missense Mutation (SNP) | VAF 90/206 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.062); catalogued as rs746354566, COSV99076308; called by muse, mutect2, varscan2
- ASPM | c.5657G>A p.R1886H | Missense Mutation (SNP) | VAF 193/703 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs558778372; called by muse, mutect2, varscan2
- ASTN2 | c.3901G>A p.E1301K (on ENST00000313400 / NM_001365069.1; = p.E1250K on NM_014010.5) | Missense Mutation (SNP) | VAF 174/446 reads (39%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.566); catalogued as rs759956720; called by muse, mutect2, varscan2
- ASXL3 | c.6110dup p.P2038Tfs*10 | Frame Shift Ins (INS) | VAF 70/177 reads (40%) | catalogued as rs747712363; called by mutect2, varscan2
- ATAD2B | c.1404del p.F468Lfs*9 | Frame Shift Del (DEL) | VAF 28/75 reads (37%) | catalogued as rs866490133; called by mutect2, pindel, varscan2
- ATG4B | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 57/170 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1460485360, COSV100728547; called by muse, mutect2, varscan2
- ATG4B | c.931G>A p.A311T | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as rs1256956340; called by muse, mutect2, varscan2
- ATP1A1 | c.998C>T p.P333L | Missense Mutation (SNP) | VAF 157/358 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1401759980, COSV55190063; called by muse, mutect2, varscan2
- ATP2B3 | c.1018G>T p.G340W | Missense Mutation (SNP) | VAF 69/79 reads (87%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1557009405; called by muse, mutect2, varscan2
- ATP2B4 | c.261dup p.K88Qfs*40 | Frame Shift Ins (INS) | VAF 68/307 reads (22%) | catalogued as rs769726180; called by mutect2, varscan2
- ATP5PO | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.058); catalogued as rs752643259; called by muse, mutect2, varscan2
- ATP8A1 | c.2546C>T p.A849V | Missense Mutation (SNP) | VAF 38/132 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.244); catalogued as COSV100047510; called by muse, mutect2, varscan2
- ATP9B | c.2959G>A p.V987M | Missense Mutation (SNP) | VAF 50/124 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1003797801, COSV56964143; called by muse, mutect2, varscan2
- ATXN1L | c.1623dup p.E542Rfs*47 | Frame Shift Ins (INS) | VAF 104/306 reads (34%) | catalogued as rs775793808; called by mutect2, varscan2
- B3GALT5 | c.706G>A p.V236I | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.149); catalogued as rs369365169; called by muse, mutect2, varscan2
- B3GLCT | c.1285A>G p.S429G | Missense Mutation (SNP) | VAF 205/986 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as rs1334170890; called by muse, mutect2, varscan2
- B3GNT9 | c.606del p.F202Lfs*3 | Frame Shift Del (DEL) | VAF 160/415 reads (39%) | catalogued as rs760854232; called by mutect2, pindel, varscan2
- BABAM2 | c.488del p.N163Tfs*13 | Frame Shift Del (DEL) | VAF 14/33 reads (42%) | catalogued as COSV59620972; called by mutect2, varscan2
- BAIAP3 | c.2021G>A p.R674H | Missense Mutation (SNP) | VAF 148/370 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs780577265, COSV50103566; called by muse, mutect2, varscan2
- BAZ2B | c.2166_2168del p.S723del | In Frame Del (DEL) | VAF 40/104 reads (38%) | catalogued as rs752085908; called by pindel, varscan2
- BBX | c.2758C>T p.L920F (on ENST00000325805 / NM_001142568.3; = p.L890F on NM_020235.7) | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs1292038730; called by muse, mutect2
- BCAS3 | c.1806del p.D603Ifs*7 (on ENST00000390652 / NM_001353144.2; = p.D588Ifs*7 on NM_017679.5 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV101177638; called by mutect2, pindel, varscan2
- BCL6B | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.45); PolyPhen benign (0.107); catalogued as rs768779742, COSV53427843; called by muse, mutect2, varscan2
- BCL9 | c.3535C>T p.R1179C | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.649); catalogued as rs144064932; called by muse, mutect2, varscan2
- BICRA | c.2935del p.A979Pfs*67 | Frame Shift Del (DEL) | VAF 16/44 reads (36%) | catalogued as rs756990560, COSV67605323; called by mutect2, pindel, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 29/165 reads (18%) | catalogued as rs772920507, COSV65808737; called by pindel, varscan2
- BNC2 | c.2563G>A p.V855I | Missense Mutation (SNP) | VAF 192/436 reads (44%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.988); catalogued as rs747700365, COSV101032323; called by muse, mutect2, varscan2
- BRAF | c.1327C>A p.P443T (on ENST00000288602 / NM_001374244.1; = p.P403T on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.24); PolyPhen probably damaging (1); catalogued as rs749792302; called by mutect2, varscan2
- BRPF3 | c.2953G>A p.E985K | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs769975719; called by muse, mutect2, varscan2
- C12orf45 | c.551del p.K184Rfs*13 | Frame Shift Del (DEL) | VAF 18/54 reads (33%) | catalogued as rs777032057; called by mutect2, varscan2
- C14orf39 | c.818_821del p.S273Nfs*11 | Frame Shift Del (DEL) | VAF 7/40 reads (18%) | catalogued as rs1267891098; called by mutect2, pindel, varscan2
- C20orf204 | c.366_367del p.R122Sfs*? | Frame Shift Del (DEL) | VAF 46/174 reads (26%) | catalogued as rs1473664174; called by pindel, varscan2
- C2CD2 | c.1307C>T p.P436L | Missense Mutation (SNP) | VAF 45/105 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs753460957; called by muse, mutect2, varscan2
- C2orf81 | c.1135C>T p.R379C | Missense Mutation (SNP) | VAF 82/185 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as rs771214248; called by muse, mutect2, varscan2
- C4BPA | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 87/150 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65537868; called by muse, mutect2, varscan2
- C7orf57 | c.506del p.K169Sfs*2 | Frame Shift Del (DEL) | VAF 54/124 reads (44%) | catalogued as rs747591930; called by mutect2, varscan2
- C8orf48 | c.184C>A p.P62T | Missense Mutation (SNP) | VAF 94/190 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1446758852; called by muse, mutect2, varscan2
- C8orf74 | c.784C>A p.P262T | Missense Mutation (SNP) | VAF 78/177 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.88); catalogued as COSV58753569; called by muse, mutect2, varscan2
- CACNA1I | c.3331G>A p.D1111N | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs1488247090; called by muse, mutect2, varscan2
- CACNB1 | c.118C>T p.R40W | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs780735037, COSV60000049; called by muse, mutect2, varscan2
- CACNG3 | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1369579426, COSV50072955; called by muse, varscan2
- CALML5 | c.304G>A p.E102K | Missense Mutation (SNP) | VAF 264/670 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV66702602; called by muse, mutect2, varscan2
- CALML6 | c.443C>T p.A148V | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.124); catalogued as rs368951637, COSV57069898; called by muse, mutect2, varscan2
- CAMSAP3 | c.2353C>T p.R785W | Missense Mutation (SNP) | VAF 40/81 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1468697372; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 139/334 reads (42%) | catalogued as rs745547658; called by mutect2, varscan2
- CASKIN1 | c.2837del p.P946Rfs*56 | Frame Shift Del (DEL) | VAF 191/532 reads (36%) | catalogued as COSV100398986; called by mutect2, pindel, varscan2
- CASKIN1 | c.1027G>A p.E343K | Missense Mutation (SNP) | VAF 165/353 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779323369, COSV58873606; called by muse, mutect2, varscan2
- CASP8 | c.1294C>T p.R432* (on ENST00000432109 / NM_033355.3; = p.R449* on NM_001228.4) | Nonsense Mutation (SNP) | VAF 129/315 reads (41%) | catalogued as rs931648756, COSV51845077; called by muse, mutect2, varscan2
- CBX7 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 166/371 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.055); catalogued as rs781069596, COSV53359310; called by muse, mutect2, varscan2
- CCAR2 | c.1249del p.R417Gfs*89 | Frame Shift Del (DEL) | VAF 74/148 reads (50%) | catalogued as rs756536005; called by mutect2, varscan2
- CCDC175 | c.1895dup p.N632Kfs*6 | Frame Shift Ins (INS) | VAF 40/113 reads (35%) | catalogued as rs1198843594; called by mutect2, varscan2
- CCDC180 | c.2003A>G p.E668G | Missense Mutation (SNP) | VAF 125/274 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.028); catalogued as COSV63829931; called by muse, varscan2
- CCDC32 | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 84/231 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.003); catalogued as rs771288328; called by muse, mutect2, varscan2
- CCT8L2 | c.1385A>C p.D462A | Missense Mutation (SNP) | VAF 137/398 reads (34%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.783); catalogued as COSV100742565; called by muse, mutect2, varscan2
- CD1D | c.1000G>A p.V334I | Missense Mutation (SNP) | VAF 88/385 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs777157013, COSV63808414; called by muse, mutect2, varscan2
- CDH22 | c.1176del p.E393Sfs*24 | Frame Shift Del (DEL) | VAF 10/26 reads (38%) | catalogued as rs768497155, COSV64836926; called by mutect2, pindel, varscan2
- CDH8 | c.845A>G p.H282R | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.006); catalogued as rs1305734981, COSV54868138; called by muse, mutect2, varscan2
- CDHR2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 109/312 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs771363502, COSV56142463; called by muse, mutect2, varscan2
- CDK11B | c.2092G>A p.D698N | Missense Mutation (SNP) | VAF 89/206 reads (43%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.63); catalogued as rs765551155; called by muse, mutect2, varscan2
- CELF3 | c.754C>A p.P252T | Missense Mutation (SNP) | VAF 27/430 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99310452; called by muse, mutect2
- CEP19 | c.95G>A p.R32H | Missense Mutation (SNP) | VAF 68/138 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs374921346; called by muse, mutect2, varscan2
- CEP295 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 77/204 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as rs71480689; called by muse, mutect2, varscan2
- CERK | c.1428dup p.K477Efs*52 | Frame Shift Ins (INS) | VAF 135/396 reads (34%) | catalogued as rs761362852; called by mutect2, varscan2
- CERS1 | c.465G>T p.Q155H | Missense Mutation (SNP) | VAF 87/210 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99897291; called by muse, mutect2, varscan2
- CETN1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 51/144 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as rs1260493790, COSV59120748; called by muse, mutect2, varscan2
- CFAP53 | c.940G>A p.V314M | Missense Mutation (SNP) | VAF 144/381 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.04); catalogued as rs376463544; called by muse, mutect2, varscan2
- CGN | c.1145G>A p.R382Q | Missense Mutation (SNP) | VAF 40/131 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.772); catalogued as rs1173604731; called by muse, mutect2, varscan2
- CHD5 | c.3267dup p.G1090Rfs*38 | Frame Shift Ins (INS) | VAF 47/147 reads (32%) | catalogued as COSV99313510; called by mutect2, pindel, varscan2
- CHD5 | c.1822G>A p.V608M | Missense Mutation (SNP) | VAF 98/262 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.629); catalogued as rs772333361; called by muse, mutect2, varscan2
- CHD8 | c.4139del p.K1380Rfs*4 (on ENST00000646647 / NM_001170629.2; = p.K1101Rfs*4 on NM_020920.4) | Frame Shift Del (DEL) | VAF 28/80 reads (35%) | catalogued as rs1317458634; called by pindel, varscan2
- CHRNA3 | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 55/147 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs775325162, COSV100468651, COSV58775586; called by muse, mutect2, varscan2
- CHST13 | c.664G>A p.D222N | Missense Mutation (SNP) | VAF 14/18 reads (78%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.537); catalogued as rs755426222; called by muse, varscan2
- CKAP5 | c.2564C>T p.T855M | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.295); catalogued as rs376402034; called by muse, mutect2, varscan2
- CLCC1 | c.1531G>A p.A511T (on ENST00000356970 / NM_001377464.1; = p.A461T on NM_015127.5) | Missense Mutation (SNP) | VAF 64/195 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.013); catalogued as COSV51441282; called by muse, mutect2, varscan2
- CLCN2 | c.736G>A p.V246M | Missense Mutation (SNP) | VAF 318/748 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs41266269; called by muse, mutect2, varscan2
- CLCN4 | c.1795G>A p.V599I | Missense Mutation (SNP) | VAF 110/139 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.097); catalogued as COSV101073752; called by muse, mutect2, varscan2
- CLEC11A | c.817G>A p.G273S | Missense Mutation (SNP) | VAF 208/403 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.023); catalogued as COSV51574487; called by muse, mutect2, varscan2
- CLIP1 | c.3940G>A p.E1314K (on ENST00000620786 / NM_001247997.1; = p.E1303K on NM_002956.2) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1389738894; called by muse, mutect2, varscan2
- CNNM1 | c.2348G>A p.R783Q | Missense Mutation (SNP) | VAF 58/119 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs773406371; called by muse, mutect2, varscan2
- CNOT1 | c.2706del p.Q904Sfs*9 | Frame Shift Del (DEL) | VAF 76/236 reads (32%) | catalogued as rs1397135931, COSV55313852; called by mutect2, pindel, varscan2
- CNOT6 | c.194G>A p.R65Q | Missense Mutation (SNP) | VAF 49/110 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs773441129; called by muse, mutect2, varscan2
- CNTN2 | c.1307T>G p.I436S | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.143); catalogued as COSV59350267; called by muse, mutect2, varscan2
- CNTNAP2 | c.512G>A p.R171H | Missense Mutation (SNP) | VAF 97/334 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.104); catalogued as rs368487049; called by muse, mutect2, varscan2
- COBL | c.121dup p.H41Pfs*31 | Frame Shift Ins (INS) | VAF 126/327 reads (39%) | catalogued as rs778516787; called by mutect2, varscan2
- COL15A1 | c.3175G>A p.G1059R | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs568399322, COSV66641303; called by muse, varscan2
- COL22A1 | c.1245+1G>A p.X415_splice | Splice Site (SNP) | VAF 83/283 reads (29%) | catalogued as rs1420049612, COSV57367402; called by muse, mutect2, varscan2
- COL4A2 | c.796G>T p.G266* | Nonsense Mutation (SNP) | VAF 37/185 reads (20%) | catalogued as COSV64626225; called by muse, mutect2, varscan2
- COL5A1 | c.4050dup p.G1351Rfs*14 | Frame Shift Ins (INS) | VAF 93/300 reads (31%) | catalogued as rs758337699; called by mutect2, varscan2
- COL5A3 | c.1898C>A p.P633H | Missense Mutation (SNP) | VAF 40/94 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV104393347; called by muse, mutect2, varscan2
- COLEC12 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 92/225 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs905694157, COSV68369756; called by muse, mutect2, varscan2
- COMMD3-BMI1 | c.20_21del p.V7Afs*72 | Frame Shift Del (DEL) | VAF 26/98 reads (27%) | catalogued as rs1436830528; called by pindel, varscan2
- COPZ2 | c.285del p.F95Lfs*4 | Frame Shift Del (DEL) | VAF 78/231 reads (34%) | catalogued as rs1321940394, COSV50057919; called by mutect2, pindel, varscan2
- COX7A2 | c.96G>T p.K32N | Missense Mutation (SNP) | VAF 71/150 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.264); catalogued as COSV100034502; called by muse, mutect2, varscan2
- CPXM1 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 210/544 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs202103486; called by muse, mutect2, varscan2
- CPXM2 | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 129/325 reads (40%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV53867264; called by muse, mutect2, varscan2
- CROCC | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 124/506 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs561750754, COSV65012237; called by muse, mutect2, varscan2
- CRTAC1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 68/132 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV54008678; called by muse, mutect2, varscan2
- CSF2RA | c.560C>T p.T187M | Missense Mutation (SNP) | VAF 96/179 reads (54%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as rs758879393, COSV100817754; called by muse, mutect2, varscan2
- CSMD1 | c.4471G>A p.A1491T (on ENST00000520002; = p.A1490T on NM_033225.6) | Missense Mutation (SNP) | VAF 35/51 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs551222035, COSV59321498; called by muse, mutect2, varscan2
- CXorf56 | c.530G>A p.R177H (on ENST00000536133 / NM_001170570.2; = p.R191H on NM_022101.4) | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs1474943188; called by muse, mutect2, varscan2
- CYP11B2 | c.1018C>A p.L340M | Missense Mutation (SNP) | VAF 385/1320 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV100011354; called by muse, mutect2, varscan2
- CYP27B1 | c.1321dup p.H441Pfs*24 | Frame Shift Ins (INS) | VAF 80/330 reads (24%) | catalogued as rs1565810563; called by mutect2, pindel, varscan2
- CYP4F11 | c.1321G>A p.D441N | Missense Mutation (SNP) | VAF 40/95 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.123); catalogued as rs1169183019, COSV56126449; called by muse, mutect2, varscan2
- DAB2IP | c.3073dup p.H1025Pfs*4 (on ENST00000408936; = p.H997Pfs*4 on NM_032552.3) | Frame Shift Ins (INS) | VAF 56/134 reads (42%) | catalogued as rs751187768; called by mutect2, varscan2
- DAPK1 | c.1934C>T p.T645M | Missense Mutation (SNP) | VAF 71/153 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as rs199838944, COSV63788550; called by muse, mutect2, varscan2
- DBH | c.1817G>C p.G606A | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); catalogued as rs766225157, COSV67549759; called by muse, mutect2, varscan2
- DCUN1D4 | c.251G>T p.S84I | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as COSV100584573; called by muse, mutect2, varscan2
- DDR1 | c.1590dup p.T531Hfs*21 | Frame Shift Ins (INS) | VAF 44/115 reads (38%) | catalogued as rs771816717; called by mutect2, varscan2
- DDR2 | c.2141G>A p.R714Q | Missense Mutation (SNP) | VAF 136/570 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63369217; called by muse, mutect2, varscan2
- DDX39B | c.736-3del | Splice Region (DEL) | VAF 33/98 reads (34%) | catalogued as rs755280697; called by mutect2, pindel, varscan2
- DDX54 | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 114/256 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.068); catalogued as rs139432025; called by muse, mutect2, varscan2
- DENND1C | c.89C>A p.P30H | Missense Mutation (SNP) | VAF 121/291 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.039); catalogued as rs764976091, COSV101200151; called by muse, mutect2, varscan2
- DGKA | c.2176dup p.R726Pfs*79 | Frame Shift Ins (INS) | VAF 68/140 reads (49%) | catalogued as rs748318989; called by mutect2, varscan2
- DGKQ | c.1228G>A p.V410M | Missense Mutation (SNP) | VAF 84/203 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.13); catalogued as rs762561319; called by muse, mutect2, varscan2
- DHX38 | c.3626G>A p.R1209Q | Missense Mutation (SNP) | VAF 80/196 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as rs777419050, COSV51701675, COSV99194268; called by muse, mutect2, varscan2
- DIPK2A | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 84/177 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.989); catalogued as rs768371725; called by muse, mutect2, varscan2
- DIS3L2 | c.2408G>A p.R803Q | Missense Mutation (SNP) | VAF 106/211 reads (50%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as rs764157950; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DISC1 | c.1634+2T>C p.X545_splice | Splice Site (SNP) | VAF 19/53 reads (36%) | catalogued as rs898672653; called by muse, mutect2, varscan2
- DMBT1 | c.580G>A p.G194S | Missense Mutation (SNP) | VAF 99/223 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs1332677197; called by muse, mutect2, varscan2
- DMRT2 | c.105del p.S38Afs*80 | Frame Shift Del (DEL) | VAF 14/52 reads (27%) | catalogued as rs1234829240; called by pindel, varscan2
- DNAAF1 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 40/383 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs538582505; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH7 | c.6859G>A p.A2287T | Missense Mutation (SNP) | VAF 113/262 reads (43%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs778594893; called by muse, mutect2, varscan2
- DNAH9 | c.3576+1G>A p.X1192_splice | Splice Site (SNP) | VAF 39/93 reads (42%) | catalogued as rs1474704926; called by muse, mutect2, varscan2
- DNAJC5G | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 117/318 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.328); catalogued as rs550880968; called by muse, mutect2, varscan2
- DOCK5 | c.4033del p.R1345Gfs*12 | Frame Shift Del (DEL) | VAF 33/106 reads (31%) | catalogued as rs1239294263; called by pindel, varscan2
- DOCK6 | c.2506G>A p.V836I | Missense Mutation (SNP) | VAF 52/122 reads (43%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as rs200935357; ClinVar: benign; called by muse, mutect2, varscan2
- DOK5 | c.566G>A p.R189H | Missense Mutation (SNP) | VAF 53/138 reads (38%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as rs762333473, COSV52823021; called by muse, varscan2
- DPF3 | c.803del p.G268Afs*4 | Frame Shift Del (DEL) | VAF 36/111 reads (32%) | catalogued as rs750670452, COSV63503637; called by mutect2, pindel, varscan2
- DPP7 | c.1205del p.G402Vfs*28 | Frame Shift Del (DEL) | VAF 78/155 reads (50%) | catalogued as rs748560644; called by mutect2, varscan2
- DPYSL2 | c.1198C>T p.R400C | Missense Mutation (SNP) | VAF 54/185 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs765277758, COSV100233804; called by muse, mutect2, varscan2
- DROSHA | c.1177G>A p.E393K | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.058); catalogued as rs151137891, COSV60783878; called by muse, mutect2
- DSCAML1 | c.3643C>T p.R1215W (on ENST00000321322; = p.R1155W on NM_020693.4) | Missense Mutation (SNP) | VAF 140/408 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.828); catalogued as rs1358475816, COSV100356506; called by muse, varscan2
- DYNC1H1 | c.483del p.F161Lfs*52 | Frame Shift Del (DEL) | VAF 134/360 reads (37%) | catalogued as rs1566996283; called by mutect2, pindel, varscan2
- DYNC1H1 | c.1150A>G p.I384V | Missense Mutation (SNP) | VAF 100/238 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.309); catalogued as rs762636220; called by muse, mutect2, varscan2
- DYNC1H1 | c.3994G>A p.V1332I | Missense Mutation (SNP) | VAF 202/492 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1567005720, COSV100794155; called by muse, mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 32/86 reads (37%) | catalogued as rs772082432; called by mutect2, varscan2
- E4F1 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 245/560 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs754184318; called by muse, mutect2, varscan2
- EIF2B3 | c.450del p.A151Qfs*57 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs748937918; called by mutect2, varscan2
- EIF2B4 | c.1438G>A p.A480T (on ENST00000347454 / NM_001034116.2; = p.A479T on NM_015636.3) | Missense Mutation (SNP) | VAF 239/580 reads (41%) | SIFT tolerated (0.49); PolyPhen benign (0.017); catalogued as rs145784671; called by muse, mutect2, varscan2
- EIF4E1B | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.908); catalogued as COSV100024789; called by muse, mutect2, varscan2
- EIF5B | c.293del p.K98Rfs*83 | Frame Shift Del (DEL) | VAF 11/21 reads (52%) | catalogued as rs769971529; called by mutect2, varscan2
- ELL | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 134/319 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.013); catalogued as rs749441049; called by muse, mutect2, varscan2
- ELOA | c.1973G>T p.R658L | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV69311254; called by muse, mutect2, varscan2
- EMC1 | c.1706_1708del p.S569del | In Frame Del (DEL) | VAF 20/108 reads (19%) | catalogued as rs1372501893; called by pindel, varscan2
- EMC2 | c.379A>G p.K127E | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.373); catalogued as rs964569172; called by muse, mutect2, varscan2
- EPHA10 | c.2604del p.R869Gfs*10 | Frame Shift Del (DEL) | VAF 72/368 reads (20%) | catalogued as rs1449193125; called by pindel, varscan2
- EPPK1 | c.5963C>T p.P1988L | Missense Mutation (SNP) | VAF 126/476 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.387); catalogued as rs372536695; called by muse, mutect2
- ERBB4 | c.232C>T p.R78W | Missense Mutation (SNP) | VAF 127/329 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1277144029, COSV99621738; called by muse, mutect2, varscan2
- ERICH6B | c.950del p.K317Rfs*18 | Frame Shift Del (DEL) | VAF 157/303 reads (52%) | catalogued as rs754232917, COSV100074795; called by mutect2, pindel, varscan2
- ERO1A | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 17/57 reads (30%) | catalogued as COSV67472303; called by muse, mutect2, varscan2
- ESR1 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 203/462 reads (44%) | SIFT tolerated (0.05); PolyPhen benign (0.202); catalogued as COSV52786782; called by muse, mutect2, varscan2
- ESYT3 | c.295C>T p.R99C | Missense Mutation (SNP) | VAF 98/240 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); catalogued as rs1261709242; called by muse, mutect2, varscan2
- ETV6 | c.1196G>C p.R399P | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56765947; called by muse, mutect2, varscan2
- FAM107B | c.-122-5del | Splice Region (DEL) | VAF 28/87 reads (32%) | catalogued as rs756478120; called by mutect2, varscan2
- FAM117B | c.1522A>G p.S508G | Missense Mutation (SNP) | VAF 108/207 reads (52%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.941); catalogued as rs1287483888; called by muse, mutect2, varscan2
- FAM124B | c.1088T>C p.V363A | Missense Mutation (SNP) | VAF 195/523 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1234853008; called by muse, mutect2, varscan2
- FAM149B1 | c.3_5del p.M1? | Translation Start Site (DEL) | VAF 6/57 reads (11%) | catalogued as rs3834904; called by pindel, varscan2*
- FAM167A | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 251/594 reads (42%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.909); catalogued as rs1453549583, COSV52671404; called by muse, mutect2, varscan2
- FAM204A | c.454-5del | Splice Region (DEL) | VAF 25/53 reads (47%) | catalogued as rs762037366; called by mutect2, varscan2
- FAM222A | c.1100T>C p.V367A | Missense Mutation (SNP) | VAF 162/424 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1230981917; called by mutect2, varscan2
- FAM47C | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 9/157 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100792423; called by muse, mutect2
- FANCA | c.3620C>T p.A1207V | Missense Mutation (SNP) | VAF 258/589 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.122); catalogued as rs1360159551; called by muse, mutect2, varscan2
- FANCC | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 92/227 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs776429990, COSV100002546, COSV56659764; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FARSA | c.236G>A p.R79H | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as rs950716095, COSV100108939, COSV58906178; called by muse, mutect2, varscan2
- FAT1 | c.1562C>T p.T521M | Missense Mutation (SNP) | VAF 146/357 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376472322; called by muse, mutect2, varscan2
- FBXO31 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 175/439 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs755030834; called by muse, mutect2, varscan2
- FBXO32 | c.826G>A p.E276K | Missense Mutation (SNP) | VAF 121/413 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.288); catalogued as rs1322012064; called by muse, mutect2, varscan2
- FBXW8 | c.365+6C>T | Splice Region (SNP) | VAF 68/184 reads (37%) | catalogued as rs1313276023; called by muse, mutect2, varscan2
- FERD3L | c.124C>A p.P42T | Missense Mutation (SNP) | VAF 118/251 reads (47%) | SIFT tolerated (0.56); PolyPhen benign (0.014); catalogued as COSV51763074; called by mutect2, varscan2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 25/52 reads (48%) | catalogued as rs748969702; called by mutect2, varscan2
- FILIP1L | c.2247del p.K749Nfs*2 (on ENST00000354552 / NM_182909.3; = p.K509Nfs*2 on NM_014890.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 118/282 reads (42%) | catalogued as COSV58769165; called by mutect2, varscan2
- FOXJ2 | c.1061C>T p.A354V | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs201863216; called by muse, mutect2, varscan2
- FRAS1 | c.10378G>A p.A3460T | Missense Mutation (SNP) | VAF 57/99 reads (58%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.723); catalogued as rs755913689, COSV53651151; called by muse, mutect2, varscan2
- FRMD4A | c.1139C>T p.S380L | Missense Mutation (SNP) | VAF 73/160 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); catalogued as rs771791704, COSV99198610; called by muse, mutect2, varscan2
- FRY | c.499C>T p.R167W | Missense Mutation (SNP) | VAF 52/253 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs773842653; called by muse, mutect2, varscan2
- FUT7 | c.223C>A p.R75S | Missense Mutation (SNP) | VAF 220/553 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV55799482; called by muse, varscan2
- FYB1 | c.972dup p.P325Afs*43 | Frame Shift Ins (INS) | VAF 77/232 reads (33%) | catalogued as rs748874978; called by mutect2, varscan2
- FZD3 | c.665del p.L222* | Frame Shift Del (DEL) | VAF 127/375 reads (34%) | catalogued as rs1563392571; called by mutect2, pindel, varscan2
- GAMT | c.355G>T p.D119Y | Missense Mutation (SNP) | VAF 55/129 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as COSV99282635; called by muse, mutect2, varscan2
- GBA2 | c.548G>A p.R183Q | Missense Mutation (SNP) | VAF 106/245 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs202051129, COSV65240539; called by muse, mutect2, varscan2
- GBP3 | c.1753del p.T585Pfs*9 | Frame Shift Del (DEL) | VAF 25/56 reads (45%) | catalogued as rs548474277; called by mutect2, varscan2
- GBP5 | c.731dup p.L245Afs*5 | Frame Shift Ins (INS) | VAF 52/177 reads (29%) | catalogued as rs34148688; called by mutect2, varscan2
- GBX2 | c.254G>A p.S85N | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.071); catalogued as COSV60445538; called by muse, varscan2
- GCK | c.1003G>A p.V335M | Missense Mutation (SNP) | VAF 188/502 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.572); catalogued as CD1310379; called by muse, mutect2, varscan2
- GEMIN4 | c.664G>A p.G222R | Missense Mutation (SNP) | VAF 121/287 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766227506; called by muse, mutect2, varscan2
- GIGYF1 | c.331dup p.L111Pfs*20 | Frame Shift Ins (INS) | VAF 64/198 reads (32%) | catalogued as rs763147690; called by mutect2, varscan2
- GJC2 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 296/1017 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1198384277; called by muse, mutect2, varscan2
- GOT1L1 | c.1243del p.T415Hfs*2 | Frame Shift Del (DEL) | VAF 45/89 reads (51%) | catalogued as rs370114090; called by mutect2, varscan2
- GPATCH2L | c.143G>A p.R48H | Missense Mutation (SNP) | VAF 111/301 reads (37%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1341319109, COSV55048302; called by muse, mutect2, varscan2
- GPR37L1 | c.398T>C p.I133T | Missense Mutation (SNP) | VAF 129/457 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as rs1203606918, COSV66161913; called by muse, mutect2, varscan2
- GPR4 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 101/222 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.79); catalogued as rs745312311, COSV59916493; called by muse, mutect2, varscan2
- GPR6 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 69/128 reads (54%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV51574216; called by muse, mutect2, varscan2
- GRB7 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761471159; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 34/104 reads (33%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIK3 | c.2590G>A p.D864N | Missense Mutation (SNP) | VAF 46/127 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.21); catalogued as rs1240292513, COSV66138442; called by muse, mutect2, varscan2
- GRIN2D | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 74/156 reads (47%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.511); catalogued as rs1335920330, COSV99616747; called by muse, mutect2, varscan2
- GRM1 | c.3131C>T p.A1044V | Missense Mutation (SNP) | VAF 56/152 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV51291708; called by muse, mutect2
- GRXCR2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 124/267 reads (46%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as rs760891258; called by muse, mutect2, varscan2
- GSE1 | c.366dup p.V123Rfs*17 | Frame Shift Ins (INS) | VAF 78/211 reads (37%) | catalogued as rs754199513; called by mutect2, varscan2
- GTF3C1 | c.1907C>T p.T636M | Missense Mutation (SNP) | VAF 87/202 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as rs144027406; called by muse, mutect2, varscan2
- GTF3C1 | c.1466G>A p.R489Q | Missense Mutation (SNP) | VAF 158/352 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.091); catalogued as rs760245565; called by muse, mutect2, varscan2
- H2BC3 | c.84G>T p.K28N | Missense Mutation (SNP) | VAF 52/128 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.304); catalogued as COSV100778234, COSV100778329; called by muse, mutect2, varscan2
- HAUS3 | c.40del p.I14Lfs*27 | Frame Shift Del (DEL) | VAF 24/61 reads (39%) | catalogued as rs748396956; called by mutect2, varscan2
- HDAC10 | c.1045G>A p.A349T | Missense Mutation (SNP) | VAF 138/320 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.062); catalogued as rs1333203256; called by muse, mutect2, varscan2
- HEXA | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 170/405 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as rs757119445; called by muse, mutect2, varscan2
- HGH1 | c.907C>T p.R303W | Missense Mutation (SNP) | VAF 394/1437 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1310203452; called by muse, mutect2, varscan2
- HGS | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 72/160 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1328226334; called by muse, mutect2, varscan2
- HIRIP3 | c.136_138del p.E46del | In Frame Del (DEL) | VAF 63/170 reads (37%) | catalogued as rs771608969; called by pindel, varscan2
- HK2 | c.73T>C p.Y25H | Missense Mutation (SNP) | VAF 107/279 reads (38%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.979); catalogued as rs376757872; called by muse, mutect2, varscan2
- HK3 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 58/168 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs186159698; called by muse, mutect2, varscan2
- HMCN2 | c.4590dup p.T1531Hfs*24 | Frame Shift Ins (INS) | VAF 42/117 reads (36%) | catalogued as rs1485731989; called by mutect2, pindel, varscan2
- HMMR | c.1998del p.K666Nfs*11 | Frame Shift Del (DEL) | VAF 28/56 reads (50%) | catalogued as rs761272507; called by mutect2, varscan2
- HOXD10 | c.848_849del p.K283Rfs*18 | Frame Shift Del (DEL) | VAF 64/176 reads (36%) | catalogued as rs1242151127; called by mutect2, pindel, varscan2
- HOXD8 | c.329del p.P110Lfs*67 | Frame Shift Del (DEL) | VAF 35/95 reads (37%) | catalogued as rs770632206; called by mutect2, pindel, varscan2
- HSP90B1 | c.743C>T p.T248I | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.775); catalogued as rs751992055, COSV55355979; called by muse, mutect2
- HSPB7 | c.57_59del p.S25del | In Frame Del (DEL) | VAF 124/290 reads (43%) | catalogued as rs769440200; called by mutect2, varscan2
- HSPG2 | c.8254G>A p.G2752R | Missense Mutation (SNP) | VAF 222/539 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs143734280; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HYAL1 | c.925del p.E309Rfs*14 | Frame Shift Del (DEL) | VAF 81/230 reads (35%) | catalogued as COSV56498185; called by mutect2, pindel, varscan2
- ICAM3 | c.668del p.P223Rfs*21 | Frame Shift Del (DEL) | VAF 141/387 reads (36%) | catalogued as rs759151580; called by mutect2, pindel, varscan2
- IDE | c.1706del p.L569Cfs*45 | Frame Shift Del (DEL) | VAF 26/67 reads (39%) | catalogued as rs771790236; called by mutect2, varscan2
- IFFO1 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 65/141 reads (46%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1164644419, COSV59109191; called by muse, mutect2, varscan2
- IGFN1 | c.2498C>T p.S833L (on ENST00000295591 / NM_001367841.1; = p.S3290L on NM_001164586.2) | Missense Mutation (SNP) | VAF 203/319 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs377537016; called by muse, mutect2, varscan2
- IGKV1-12 | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 153/694 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.041); catalogued as rs764773736; called by muse, mutect2
- IGKV1D-17 | c.256G>A p.G86S | Missense Mutation (SNP) | VAF 211/787 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.83); catalogued as rs567222572; called by muse, mutect2, varscan2
- IL17RC | c.589G>A p.V197M (on ENST00000295981 / NM_153461.4; = p.V126M on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1460510963, COSV99924915; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ILDR1 | c.775C>T p.R259* | Nonsense Mutation (SNP) | VAF 53/133 reads (40%) | catalogued as rs920852517, COSV56551086; called by muse, mutect2, varscan2
- INAVA | c.1790G>A p.R597H | Missense Mutation (SNP) | VAF 253/450 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as COSV66255953; called by muse, varscan2
- INO80B | c.1035del p.E347Rfs*? | Frame Shift Del (DEL) | VAF 45/126 reads (36%) | catalogued as rs752165206; called by mutect2, pindel, varscan2
- INO80E | c.633del p.T212Rfs*3 | Frame Shift Del (DEL) | VAF 14/23 reads (61%) | catalogued as rs759306300, COSV58752155, COSV58752733; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 116/312 reads (37%) | catalogued as rs760925109; called by mutect2, varscan2
- INSYN2A | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 273/720 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.178); catalogued as COSV54738233; called by muse, mutect2, varscan2
- INTS1 | c.5147C>A p.P1716Q | Missense Mutation (SNP) | VAF 134/306 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV101247296; called by muse, varscan2
- IQGAP2 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 74/164 reads (45%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs138552758; called by muse, mutect2, varscan2
- IRGQ | c.349C>T p.R117C | Missense Mutation (SNP) | VAF 180/387 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.453); catalogued as rs1036484301; called by muse, mutect2, varscan2
- ITGA7 | c.955C>T p.R319C (on ENST00000555728; = p.R275C on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 272/666 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs748061315; called by muse, varscan2
- ITSN1 | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as rs963769471, COSV101180514, COSV101180598; called by muse, mutect2, varscan2
- KCNA1 | c.1312G>A p.D438N | Missense Mutation (SNP) | VAF 185/366 reads (51%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV101230287; called by muse, mutect2, varscan2
- KCP | c.4040G>A p.R1347Q (on ENST00000620378; = p.R1471Q on NM_001366122.1) | Missense Mutation (SNP) | VAF 239/634 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.283); catalogued as rs1209246509; called by muse, mutect2, varscan2
- KCP | c.719G>A p.R240Q (on ENST00000620378; = p.R297Q on NM_001366122.1) | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.018); catalogued as rs1350215429, COSV99925691; called by muse, mutect2, varscan2
- KHDRBS3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 50/248 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs764983380, COSV63417522; called by muse, mutect2, varscan2
- KIAA1217 | c.2275C>T p.R759C | Missense Mutation (SNP) | VAF 62/166 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1175631814; called by muse, mutect2, varscan2
- KIF21A | c.3703del p.I1235Ffs*7 (on ENST00000361418 / NM_001378440.1; = p.I1222Ffs*7 on NM_017641.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 76/172 reads (44%) | catalogued as rs761074592; called by mutect2, varscan2
- KIR3DL2 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 106/224 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.116); catalogued as rs377747595; called by muse, mutect2, varscan2
- KIRREL2 | c.815G>A p.R272H | Missense Mutation (SNP) | VAF 144/328 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.685); catalogued as rs939777968, COSV52874329; called by muse, mutect2, varscan2
- KL | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 92/452 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.26); catalogued as rs1473790474; called by muse, mutect2, varscan2
- KLF12 | c.33+2T>G p.X11_splice | Splice Site (SNP) | VAF 102/171 reads (60%) | catalogued as COSV66581499; called by muse, mutect2, varscan2
- KLF3 | c.677del p.P226Rfs*52 | Frame Shift Del (DEL) | VAF 52/106 reads (49%) | catalogued as COSV54711577; called by mutect2, pindel, varscan2
- KLHDC8A | c.88G>A p.G30R | Missense Mutation (SNP) | VAF 276/457 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.347); catalogued as rs759019062; called by muse, mutect2, varscan2
- KLHL1 | c.104del p.G35Efs*31 | Frame Shift Del (DEL) | VAF 46/232 reads (20%) | catalogued as rs749011008; called by mutect2, pindel, varscan2
- KLHL40 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 24/606 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV55133790; called by muse, mutect2
- KMT2D | c.8558C>T p.P2853L | Missense Mutation (SNP) | VAF 175/364 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as rs754988293, COSV56408774; called by muse, mutect2, varscan2
- KRT16 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 336/819 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.917); catalogued as COSV56968836; called by muse, varscan2
- KRT37 | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 67/156 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.005); catalogued as rs764489269, COSV56659096; called by muse, mutect2, varscan2
- KRT81 | c.164G>A p.R55Q | Missense Mutation (SNP) | VAF 18/602 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.379); catalogued as rs1222206060; called by muse, mutect2
- L3MBTL2 | c.2053G>A p.D685N | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT tolerated, low confidence (0.49); PolyPhen benign (0); catalogued as rs201362426; called by muse, mutect2, varscan2
- L3MBTL4 | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.231); catalogued as COSV53130231; called by muse, mutect2, varscan2
- LAMA1 | c.7184A>G p.N2395S | Missense Mutation (SNP) | VAF 125/343 reads (36%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.974); catalogued as rs1380688607, COSV101055389; called by muse, mutect2, varscan2
- LAMB4 | c.196del p.E66Nfs*29 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | catalogued as rs753541717; called by mutect2, pindel, varscan2
- LGALS1 | c.355A>C p.N119H | Missense Mutation (SNP) | VAF 79/212 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV99313818; called by muse, mutect2, varscan2
- LILRB2 | c.1283del p.P428Hfs*35 | Frame Shift Del (DEL) | VAF 53/159 reads (33%) | catalogued as rs1281849477; called by mutect2, pindel, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 54/126 reads (43%) | catalogued as rs780042765; called by mutect2, varscan2
- LONRF2 | c.713C>T p.A238V | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.826); catalogued as rs1176119486, COSV66539664; called by muse, mutect2, varscan2
- LPA | c.3644A>C p.N1215T | Missense Mutation (SNP) | VAF 18/280 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV60296923; called by muse, mutect2
- LPA | c.2503C>T p.R835* | Nonsense Mutation (SNP) | VAF 48/270 reads (18%) | catalogued as rs746733669, COSV100305985; called by muse, mutect2
- LPIN3 | c.335dup p.L113Sfs*15 | Frame Shift Ins (INS) | VAF 31/275 reads (11%) | catalogued as rs756955559; called by mutect2, varscan2
- LRP1 | c.12575del p.P4192Qfs*150 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | catalogued as rs757410385; called by mutect2, varscan2
- LRP1B | c.3199G>A p.V1067I | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs745676943, COSV67259843; called by muse, mutect2, varscan2
- LRP2 | c.7514G>A p.R2505H | Missense Mutation (SNP) | VAF 214/488 reads (44%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs371708810; called by muse, varscan2
- LRRC69 | c.914G>A p.R305Q | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs976516885, COSV59250589; called by muse, mutect2, varscan2
- LRRK2 | c.4915dup p.R1639Kfs*13 | Frame Shift Ins (INS) | VAF 42/110 reads (38%) | catalogued as rs756089224; called by mutect2, varscan2
- LSS | c.1661C>T p.A554V | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs763701401; called by muse, mutect2
- LTBP1 | c.3934G>A p.V1312M (on ENST00000404816 / NM_206943.4; = p.V986M on NM_000627.4) | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs780061448; called by muse, mutect2, varscan2
- LTBP4 | c.4224dup p.A1409Rfs*3 (on ENST00000308370 / NM_001042544.1; = p.A1372Rfs*3 on NM_003573.2) | Frame Shift Ins (INS) | VAF 37/112 reads (33%) | catalogued as rs754757253; called by mutect2, varscan2
- LZTR1 | c.1396C>T p.R466W | Missense Mutation (SNP) | VAF 122/304 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550922200, COSV99301431; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MACF1 | c.5468C>T p.T1823M | Missense Mutation (SNP) | VAF 121/297 reads (41%) | catalogued as rs202109384; called by muse, mutect2, varscan2
- MAFA | c.685G>A p.D229N | Missense Mutation (SNP) | VAF 150/453 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1005045208; called by muse, mutect2, varscan2
- MAG | c.412G>A p.V138I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781042421; called by muse, mutect2, varscan2
- MAP2K7 | c.827G>A p.R276Q | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as COSV67608956; called by muse, mutect2, varscan2
- MBD6 | c.2345del p.G782Efs*13 | Frame Shift Del (DEL) | VAF 32/92 reads (35%) | catalogued as rs746267361; called by mutect2, varscan2
- MCHR2 | c.623del p.F208Sfs*5 | Frame Shift Del (DEL) | VAF 26/58 reads (45%) | catalogued as rs759525627, COSV55999002; called by mutect2, varscan2
- MCHR2 | c.284G>A p.R95Q | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.009); catalogued as rs1015907823, COSV56002006, COSV99912673; called by muse, mutect2, varscan2
- MDGA2 | c.1206del p.G403Dfs*22 (on ENST00000399232 / NM_001113498.2; = p.G105Dfs*22 on NM_182830.4) | Frame Shift Del (DEL) | VAF 38/94 reads (40%) | catalogued as rs1180255648; called by mutect2, varscan2
- MDGA2 | c.56G>T p.R19M | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.711); catalogued as COSV67795818; called by muse, varscan2
- MDN1 | c.12865C>T p.R4289C | Missense Mutation (SNP) | VAF 65/187 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs766037169; called by muse, mutect2, varscan2
- MED1 | c.437del p.N146Ifs*24 | Frame Shift Del (DEL) | VAF 15/39 reads (38%) | catalogued as COSV56125174; called by mutect2, pindel, varscan2
- MEN1 | c.670-5dup | Splice Region (INS) | VAF 185/466 reads (40%) | catalogued as rs772016629; ClinVar: benign / likely benign; called by mutect2, varscan2
- MEPCE | c.434del p.G145Afs*11 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | catalogued as rs760012501; called by mutect2, varscan2
- MFSD14A | c.806del p.L269Yfs*6 | Frame Shift Del (DEL) | VAF 58/119 reads (49%) | catalogued as rs780635289; called by mutect2, varscan2
- MFSD2B | c.1138G>A p.V380M | Missense Mutation (SNP) | VAF 111/253 reads (44%) | SIFT tolerated (0.16); PolyPhen benign (0.165); catalogued as rs759338733, COSV57854737; called by muse, mutect2, varscan2
- MFSD8 | c.831dup p.V278Cfs*10 | Frame Shift Ins (INS) | VAF 23/81 reads (28%) | catalogued as rs775699005; called by mutect2, pindel, varscan2
- MGAM2 | c.1936G>A p.A646T | Missense Mutation (SNP) | VAF 58/116 reads (50%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs966543041; called by muse, mutect2, varscan2
- MGAT4C | c.1370G>T p.R457M | Missense Mutation (SNP) | VAF 60/158 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV59834503; called by muse, mutect2
- MIA2 | c.1089del p.D364Tfs*8 | Frame Shift Del (DEL) | VAF 36/84 reads (43%) | catalogued as rs538500709; called by mutect2, varscan2
- MIDEAS | c.939del p.N314Tfs*4 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as rs762448666; called by mutect2, pindel, varscan2
- MMP25 | c.1575del p.V526Cfs*34 | Frame Shift Del (DEL) | VAF 80/210 reads (38%) | catalogued as rs747774238; called by pindel, varscan2
- MMP3 | c.190dup p.I64Nfs*33 | Frame Shift Ins (INS) | VAF 64/148 reads (43%) | catalogued as rs782038929; called by mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 68/246 reads (28%) | catalogued as rs755830405; called by mutect2, varscan2
- MRAS | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 74/158 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV56675173; called by muse, varscan2
- MRE11 | c.1532del p.N511Ifs*13 | Frame Shift Del (DEL) | VAF 79/217 reads (36%) | catalogued as rs757691558; called by mutect2, pindel, varscan2
- MROH1 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs937188035, COSV58194252; called by muse, mutect2, varscan2
- MRPL15 | c.560T>C p.V187A | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99477467; called by muse, mutect2, varscan2
- MRPS12 | c.155C>T p.T52M | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.114); catalogued as rs368555992; called by muse, mutect2, varscan2
- MRTFB | c.3242C>T p.P1081L (on ENST00000571589 / NM_001365412.2; = p.P1031L on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/98 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs752641140; called by muse, varscan2
- MST1R | c.1058G>A p.G353D | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT tolerated (0.21); PolyPhen benign (0.042); catalogued as rs777931738; called by muse, mutect2, varscan2
- MTMR3 | c.836G>A p.R279Q | Missense Mutation (SNP) | VAF 147/410 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.19); catalogued as rs767584169, COSV60305083; called by muse, mutect2, varscan2
- MUC5B | c.15103C>T p.R5035C | Missense Mutation (SNP) | VAF 351/885 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs769579721, COSV71592640; called by muse, mutect2, varscan2
- MYH15 | c.23C>T p.T8M | Missense Mutation (SNP) | VAF 46/88 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.006); catalogued as rs200229973; called by muse, mutect2, varscan2
- MYH6 | c.2098G>A p.V700M | Missense Mutation (SNP) | VAF 398/928 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs767142932, CM107533, COSV100676802; called by muse, varscan2
- MYH7B | c.2987C>T p.T996M | Missense Mutation (SNP) | VAF 148/424 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); catalogued as rs202055718, COSV53421033; called by muse, mutect2, varscan2
- MYO10 | c.2234C>T p.A745V | Missense Mutation (SNP) | VAF 54/138 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.63); catalogued as rs776810367, COSV57016325; called by muse, mutect2, varscan2
- MYO18A | c.5696G>A p.R1899H | Missense Mutation (SNP) | VAF 74/188 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs769195242, COSV62861995; called by muse, mutect2, varscan2
- MYOM2 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 78/113 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV50761673; called by muse, mutect2, varscan2
- MYPN | c.916G>A p.G306S | Missense Mutation (SNP) | VAF 112/344 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs944386602; called by muse, mutect2, varscan2
- MYRF | c.2480G>A p.C827Y | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1324140673; called by muse, mutect2, varscan2
- MZT2A | c.440dup p.G148Rfs*34 | Frame Shift Ins (INS) | VAF 69/163 reads (42%) | catalogued as rs753638030; called by mutect2, pindel, varscan2
- NARF | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 42/88 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.051); catalogued as rs746481691, COSV59111184; called by muse, varscan2
- NBEA | c.4187C>T p.A1396V | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59766566; called by muse, mutect2, varscan2
- NBPF9 | c.510G>T p.E170D | Missense Mutation (SNP) | VAF 160/270 reads (59%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.955); catalogued as COSV100977967; called by muse, mutect2, varscan2
- NDNF | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.984); catalogued as rs199541505; called by muse, mutect2, varscan2
- NEB | c.2783del p.P928Lfs*29 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | catalogued as rs751346602; called by mutect2, pindel, varscan2
- NEK2 | c.178C>T p.R60C | Missense Mutation (SNP) | VAF 98/177 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1438076471, COSV65357464; called by muse, mutect2, varscan2
- NET1 | c.1772G>A p.R591Q (on ENST00000355029 / NM_001047160.3; = p.R537Q on NM_005863.5) | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.007); catalogued as rs149626244; called by muse, mutect2, varscan2
- NIPA2 | c.98del p.K33Rfs*12 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs145147241; called by mutect2, varscan2
- NKTR | c.1847del p.P616Lfs*21 | Frame Shift Del (DEL) | VAF 39/103 reads (38%) | catalogued as rs763440516; called by mutect2, varscan2
- NLRX1 | c.2354G>A p.R785Q | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.152); catalogued as rs765127292; called by muse, mutect2, varscan2
- NOLC1 | c.840del p.K280Nfs*3 | Frame Shift Del (DEL) | VAF 50/108 reads (46%) | catalogued as rs759637346; called by mutect2, varscan2
- NOSTRIN | c.572del p.N191Tfs*9 (on ENST00000317647 / NM_001039724.4; = p.N113Tfs*9 on NM_052946.3) | Frame Shift Del (DEL) | VAF 46/157 reads (29%) | catalogued as rs1282346576; called by mutect2, pindel, varscan2
- NOTCH4 | c.4691C>T p.A1564V | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV66679414; called by muse, varscan2
- NOTUM | c.704dup p.T236Hfs*12 | Frame Shift Ins (INS) | VAF 76/254 reads (30%) | catalogued as rs778719752; called by mutect2, pindel, varscan2
- NPAP1 | c.2792C>A p.P931H | Missense Mutation (SNP) | VAF 144/375 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV61512086; called by muse, mutect2, varscan2
- NPAT | c.2786-3del | Splice Region (DEL) | VAF 41/118 reads (35%) | catalogued as rs35747263; called by mutect2, pindel, varscan2
- NR1H3 | c.601dup p.Q201Pfs*25 | Frame Shift Ins (INS) | VAF 82/218 reads (38%) | catalogued as rs779801455; called by mutect2, varscan2
- NRIP3 | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 39/97 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs368304763, COSV58469863; called by muse, mutect2, varscan2
- NUTM2G | c.1454G>A p.R485H | Missense Mutation (SNP) | VAF 72/343 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as rs551466226; called by muse, mutect2, varscan2
- OAS1 | c.392C>T p.A131V | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.91); PolyPhen benign (0.048); catalogued as rs761673884; called by muse, mutect2, varscan2
- OBSCN | c.15782A>G p.Q5261R | Missense Mutation (SNP) | VAF 28/291 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1272773811; called by muse, mutect2
- ONECUT3 | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs912568481, COSV66640062; called by muse, mutect2, varscan2
- OPRPN | c.390del p.A132Lfs*13 | Frame Shift Del (DEL) | VAF 61/163 reads (37%) | catalogued as COSV68192802; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 120/372 reads (32%) | catalogued as rs761899382; called by mutect2, varscan2
- OR1L8 | c.62G>A p.R21Q | Missense Mutation (SNP) | VAF 36/86 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1344222880, COSV100508717, COSV59187538; called by muse, mutect2, varscan2
- OR3A1 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 61/145 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.292); catalogued as rs540886927, COSV60163122; called by muse, mutect2, varscan2
- OR4A15 | c.634A>C p.I212L | Missense Mutation (SNP) | VAF 78/372 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs539581929, COSV100124325; called by muse, mutect2, varscan2
- OR4X2 | c.50G>A p.R17K | Missense Mutation (SNP) | VAF 57/162 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs746420613; called by muse, mutect2, varscan2
- OR5V1 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 13/374 reads (3%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV65826589; called by muse, mutect2
- OSGEPL1 | c.36del p.F12Lfs*12 | Frame Shift Del (DEL) | VAF 34/67 reads (51%) | catalogued as rs750679212; called by mutect2, varscan2
- P2RX7 | c.829C>T p.R277C | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs574145347; called by muse, mutect2, varscan2
- PAK4 | c.196del p.A66Pfs*29 | Frame Shift Del (DEL) | VAF 116/321 reads (36%) | catalogued as COSV100426419; called by mutect2, pindel, varscan2
- PBXIP1 | c.946del p.A316Lfs*66 | Frame Shift Del (DEL) | VAF 35/172 reads (20%) | catalogued as rs778137001, COSV63776880; called by mutect2, pindel, varscan2
- PCDHB14 | c.2135G>A p.R712Q | Missense Mutation (SNP) | VAF 176/547 reads (32%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.135); catalogued as rs1231139852; called by muse, mutect2, varscan2
- PCDHB7 | c.1797C>A p.N599K | Missense Mutation (SNP) | VAF 469/1406 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs782476678, COSV50763273; called by muse, mutect2, varscan2
- PCDHGB6 | c.1576C>T p.R526C | Missense Mutation (SNP) | VAF 187/439 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53910872; called by muse, mutect2, varscan2
- PCGF1 | c.565-6T>A | Splice Region (SNP) | VAF 136/404 reads (34%) | catalogued as rs755387225; called by muse, mutect2, varscan2
- PCLO | c.7265del p.P2422Lfs*22 | Frame Shift Del (DEL) | VAF 54/158 reads (34%) | catalogued as rs1262793592; called by pindel, varscan2
- PCNT | c.4180del p.E1394Rfs*21 | Frame Shift Del (DEL) | VAF 38/302 reads (13%) | catalogued as rs755265991; called by mutect2, varscan2
- PDE3A | c.511dup p.E171Gfs*49 | Frame Shift Ins (INS) | VAF 90/346 reads (26%) | catalogued as rs780389664; called by mutect2, varscan2
- PDE7A | c.1179del p.K393Nfs*6 (on ENST00000401827 / NM_001242318.3; = p.K367Nfs*6 on NM_002603.4) | Frame Shift Del (DEL) | VAF 8/32 reads (25%) | catalogued as rs776556726; called by mutect2, varscan2
- PDS5B | c.3954del p.K1318Nfs*76 | Frame Shift Del (DEL) | VAF 35/170 reads (21%) | catalogued as rs747131399; called by mutect2, varscan2
- PERM1 | c.1901C>T p.P634L | Missense Mutation (SNP) | VAF 36/211 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.054); catalogued as rs937152501, COSV100379107; called by muse, mutect2, varscan2
- PHACTR2 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 100/246 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs201153372, COSV59853916; called by muse, mutect2, varscan2
- PHF2 | c.1475del p.K492Rfs*6 | Frame Shift Del (DEL) | VAF 62/156 reads (40%) | catalogued as rs769717544; called by mutect2, varscan2
- PHF20L1 | c.1721del p.K574Rfs*28 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | catalogued as rs772333737; called by mutect2, varscan2
- PHYHIPL | c.1072A>G p.T358A | Missense Mutation (SNP) | VAF 78/137 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.611); catalogued as rs748585130; called by muse, mutect2, varscan2
- PIK3CG | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 119/289 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752039271, COSV63246252; called by muse, mutect2, varscan2
- PISD | c.662C>T p.P221L (on ENST00000439502 / NM_001326412.1; = p.P187L on NM_014338.3) | Missense Mutation (SNP) | VAF 93/189 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as rs754079183, COSV99837196; called by muse, mutect2, varscan2
- PKD1 | c.10260G>A p.W3420* (on ENST00000262304 / NM_001009944.3; = p.W3419* on NM_000296.4) | Nonsense Mutation (SNP) | VAF 193/420 reads (46%) | catalogued as CM076427; called by muse, mutect2, varscan2
- PKD1 | c.8408G>A p.G2803D | Missense Mutation (SNP) | VAF 30/930 reads (3%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as rs1368840123, COSV51922811; called by muse, mutect2
- PKD1L1 | c.314C>T p.A105V | Missense Mutation (SNP) | VAF 54/142 reads (38%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0); catalogued as rs147759458; called by muse, mutect2, varscan2
- PKD2L2 | c.116dup p.L39Ffs*35 | Frame Shift Ins (INS) | VAF 18/48 reads (38%) | catalogued as rs1406261366; called by mutect2, varscan2
- PKDREJ | c.2297C>A p.P766H | Missense Mutation (SNP) | VAF 102/232 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as rs1343076958; called by muse, mutect2, varscan2
- PKLR | c.1112C>T p.T371I | Missense Mutation (SNP) | VAF 161/595 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as CM061888; called by muse, mutect2, varscan2
- PLXNB3 | c.4963del p.V1655Cfs*7 | Frame Shift Del (DEL) | VAF 78/91 reads (86%) | catalogued as rs782076287; called by mutect2, varscan2
- PLXNC1 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1166331202; called by muse, mutect2, varscan2
- PNCK | c.241G>A p.E81K (on ENST00000340888 / NM_001366975.1; = p.E164K on NM_001039582.3) | Missense Mutation (SNP) | VAF 48/56 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100562231; called by muse, mutect2, varscan2
- PNMA8A | c.259C>A p.P87T | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV58137814; called by mutect2, varscan2
- PNOC | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 110/282 reads (39%) | catalogued as COSV57283901; called by muse, mutect2, varscan2
- POFUT2 | c.37del p.A13Qfs*58 | Frame Shift Del (DEL) | VAF 22/57 reads (39%) | catalogued as rs1439374428; called by mutect2, pindel, varscan2
- POLE | c.4144C>T p.R1382C | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs5744904; ClinVar: uncertain significance; called by mutect2, varscan2
- POMC | c.755C>T p.T252M | Missense Mutation (SNP) | VAF 138/314 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs775998713, COSV53034904; called by muse, mutect2, varscan2
- POPDC2 | c.673A>G p.K225E | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as rs375598899; called by muse, mutect2, varscan2
- POT1 | c.1337C>T p.P446L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.09); PolyPhen benign (0.361); catalogued as rs761176134; called by muse, mutect2, varscan2
- POTEG | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 95/239 reads (40%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as rs758678723; called by muse, mutect2, varscan2
- POU4F2 | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.49); catalogued as rs1224071283, COSV55586501, COSV99850428; called by muse, mutect2, varscan2
- PPP1R26 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.072); catalogued as rs770647575; called by muse, mutect2, varscan2
- PRDM16 | c.686C>T p.T229M | Missense Mutation (SNP) | VAF 171/388 reads (44%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs768642626; called by muse, mutect2
- PREX2 | c.877C>T p.R293W | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs777080876, COSV55774169, COSV55804768; called by muse, mutect2, varscan2
- PREX2 | c.1693del p.S565Rfs*10 | Frame Shift Del (DEL) | VAF 42/112 reads (38%) | catalogued as rs764112302; called by mutect2, varscan2
- PREX2 | c.2370G>T p.E790D | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV99910370; called by muse, mutect2, varscan2
- PRKAG1 | c.186del p.F62Lfs*4 | Frame Shift Del (DEL) | VAF 101/267 reads (38%) | catalogued as rs1565733883; called by mutect2, pindel, varscan2
- PRKCG | c.277del p.Q93Rfs*37 | Frame Shift Del (DEL) | VAF 153/445 reads (34%) | catalogued as COSV54724284; called by mutect2, pindel, varscan2
- PRKCSH | c.914C>T p.P305L | Missense Mutation (SNP) | VAF 122/347 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs201385707; ClinVar: uncertain significance; called by muse, varscan2
- PRKD1 | c.2107G>A p.V703I | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs1274583081, COSV59561520, COSV59569146; called by muse, mutect2, varscan2
- PRKD2 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 80/198 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.986); catalogued as rs1447925115; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 11/24 reads (46%) | catalogued as rs537061158; called by mutect2, varscan2
- PROS1 | c.1795G>T p.D599Y | Missense Mutation (SNP) | VAF 62/178 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101260811, COSV67775334; called by muse, mutect2, varscan2
- PRPF31 | c.1222C>T p.R408W | Missense Mutation (SNP) | VAF 292/779 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367896277; called by muse, mutect2, varscan2
- PSD3 | c.2740_2742del p.K914del (on ENST00000440756; = p.K913del on NM_015310.4) | In Frame Del (DEL) | VAF 85/160 reads (53%) | catalogued as rs765247344; called by pindel, varscan2
- PTGFRN | c.2146G>A p.E716K | Missense Mutation (SNP) | VAF 64/154 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.058); catalogued as rs779207353; called by muse, mutect2, varscan2
- PTPRS | c.3072del p.V1025Sfs*18 | Frame Shift Del (DEL) | VAF 65/136 reads (48%) | catalogued as rs756013055, COSV53629833; called by mutect2, varscan2
- PTPRS | c.1865del p.P622Lfs*16 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs755108907; called by mutect2, pindel, varscan2
- PXMP4 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs367855619; called by muse, varscan2
- R3HDM4 | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 60/129 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs923554262; called by muse, mutect2, varscan2
- RAB8A | c.212G>A p.R71Q | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs747042137; called by muse, mutect2, varscan2
- RABGAP1 | c.2789del p.N930Tfs*15 | Frame Shift Del (DEL) | VAF 48/104 reads (46%) | catalogued as rs749213218, COSV101017169; called by mutect2, varscan2
- RAD54L | c.674A>G p.N225S | Missense Mutation (SNP) | VAF 225/487 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1412346298; called by muse, mutect2, varscan2
- RADIL | c.934G>A p.A312T | Missense Mutation (SNP) | VAF 208/480 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as rs746063859, COSV68199784; called by muse, mutect2, varscan2
- RALGDS | c.2648G>A p.R883Q | Missense Mutation (SNP) | VAF 255/606 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs776063928, COSV64426305; called by muse, mutect2, varscan2
- RAPGEF3 | c.295A>G p.R99G (on ENST00000389212; = p.R57G on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/604 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV50200768; called by muse, mutect2
- RASAL2 | c.1636C>T p.R546C | Missense Mutation (SNP) | VAF 82/306 reads (27%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.849); catalogued as rs140709606; called by muse, mutect2, varscan2
- RBM23 | c.247C>T p.R83W (on ENST00000359890 / NM_001077351.2; = p.R67W on NM_018107.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/162 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as rs760125299; called by muse, mutect2, varscan2
- RBM26 | c.2181del p.K727Nfs*5 (on ENST00000438737 / NM_001366735.2; = p.K700Nfs*5 on NM_022118.5) | Frame Shift Del (DEL) | VAF 66/113 reads (58%) | catalogued as rs751690893; called by mutect2, varscan2
- RCOR3 | c.397del p.T133Lfs*7 | Frame Shift Del (DEL) | VAF 31/136 reads (23%) | catalogued as COSV65365594; called by mutect2, pindel, varscan2
- RECQL4 | c.1154A>C p.K385T | Missense Mutation (SNP) | VAF 138/462 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV52881150; called by muse, mutect2, varscan2
- REST | c.2494C>T p.R832W | Missense Mutation (SNP) | VAF 87/237 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs367963860; called by muse, mutect2, varscan2
- RFX1 | c.1006G>T p.G336C | Missense Mutation (SNP) | VAF 159/353 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV54328849; called by muse, mutect2, varscan2
- RGL2 | c.608dup p.S204Qfs*3 | Frame Shift Ins (INS) | VAF 92/240 reads (38%) | catalogued as rs762949421; called by mutect2, varscan2
- RGS11 | c.941G>A p.R314Q (on ENST00000397770 / NM_183337.3; = p.R293Q on NM_003834.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 93/222 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); catalogued as rs546820820; called by muse, mutect2, varscan2
- RGS12 | c.3534del p.K1178Nfs*32 | Frame Shift Del (DEL) | VAF 56/72 reads (78%) | catalogued as rs753542639, COSV58750063; called by mutect2, varscan2
- RGS9 | c.1730G>A p.R577H | Missense Mutation (SNP) | VAF 226/539 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.996); catalogued as rs866147892, COSV52225793, COSV52227907; called by muse, mutect2, varscan2
- RIF1 | c.3730T>C p.S1244P | Missense Mutation (SNP) | VAF 55/135 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.388); catalogued as rs762994614; called by muse, mutect2, varscan2
- RIMS1 | c.2873G>A p.R958H | Missense Mutation (SNP) | VAF 48/118 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373238402, COSV99327156; called by muse, mutect2, varscan2
- RING1 | c.904C>T p.R302C | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as rs1183179120; called by muse, mutect2, varscan2
- RINT1 | c.1826G>A p.R609H | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs770101080, COSV57557811; called by muse, mutect2, varscan2
- RND2 | c.218C>A p.P73H | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56816786; called by muse, mutect2, varscan2
- RNF114 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 46/109 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs745318334, COSV54870771; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 170/273 reads (62%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel, varscan2
- ROR2 | c.2110G>A p.A704T | Missense Mutation (SNP) | VAF 38/102 reads (37%) | PolyPhen benign (0.003); catalogued as rs778427583; called by muse, mutect2
- RP1 | c.74G>A p.R25H | Missense Mutation (SNP) | VAF 109/327 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886062989, COSV55112474; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RP1L1 | c.2750C>T p.A917V | Missense Mutation (SNP) | VAF 28/519 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs768303030, COSV66754165; called by muse, mutect2
- RPL22 | c.289C>T p.R97C | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as COSV52379675; called by muse, mutect2, varscan2
- RPL22 | c.44del p.K15Rfs*5 | Frame Shift Del (DEL) | VAF 51/120 reads (43%) | catalogued as rs759765382, COSV52379423; called by mutect2, varscan2
- RPL7 | c.25A>G p.K9E | Missense Mutation (SNP) | VAF 51/196 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.047); catalogued as rs768798846; called by muse, mutect2, varscan2
- RPS6KA6 | c.327del p.A110Pfs*3 | Frame Shift Del (DEL) | VAF 18/35 reads (51%) | catalogued as rs756096568; called by pindel, varscan2
- RSF1 | c.1056A>T p.E352D | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as rs1467962868; called by muse, mutect2, varscan2
- RSKR | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 58/154 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV56381264; called by muse, mutect2, varscan2
- RSPH1 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 52/163 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.637); catalogued as rs373683028; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RTL5 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 49/57 reads (86%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.761); catalogued as rs747452913, COSV65453684; called by muse, mutect2, varscan2
- RTTN | c.5744del p.K1915Rfs*9 | Frame Shift Del (DEL) | VAF 32/59 reads (54%) | catalogued as rs756606313; called by mutect2, varscan2
- RYR1 | c.2489G>A p.R830Q | Missense Mutation (SNP) | VAF 256/579 reads (44%) | SIFT tolerated (0.49); PolyPhen benign (0.087); catalogued as rs777191617, COSV62095839; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RYR1 | c.4777C>T p.R1593W | Missense Mutation (SNP) | VAF 290/680 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1229854214, COSV62092457; called by muse, mutect2, varscan2
- RYR1 | c.11770C>T p.R3924W | Missense Mutation (SNP) | VAF 187/439 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100614228; called by muse, mutect2, varscan2
- RYR2 | c.6320C>T p.T2107M | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs370331492, COSV63669380; ClinVar: uncertain significance; called by muse, mutect2
- RYR2 | c.14217del p.F4739Lfs*15 | Frame Shift Del (DEL) | VAF 70/120 reads (58%) | catalogued as rs749201569; called by mutect2, varscan2
- S1PR5 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 67/153 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100330673; called by muse, mutect2, varscan2
- SAFB2 | c.2447G>A p.R816Q | Missense Mutation (SNP) | VAF 71/191 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); catalogued as rs754638228; called by muse, mutect2, varscan2
- SALL4 | c.1768G>A p.G590R | Missense Mutation (SNP) | VAF 227/564 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.818); catalogued as rs759734415; called by muse, varscan2
- SAMD4B | c.530dup p.A179Cfs*53 | Frame Shift Ins (INS) | VAF 130/336 reads (39%) | catalogued as rs761897037; called by mutect2, varscan2
- SAMSN1 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.268); catalogued as COSV53467328; called by muse, mutect2, varscan2
- SCAF4 | c.3397G>A p.V1133I | Missense Mutation (SNP) | VAF 61/175 reads (35%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs563567552, COSV54256868; called by muse, mutect2, varscan2
- SCN4A | c.2146G>A p.V716M | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs773527089, COSV71127984; called by muse, mutect2, varscan2
- SCP2 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 85/179 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV101026874; called by muse, mutect2, varscan2
- SEMA6A | c.2542G>A p.A848T | Missense Mutation (SNP) | VAF 43/550 reads (8%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.793); catalogued as rs754006049; called by muse, mutect2
- SERPINA3 | c.550G>A p.V184M | Missense Mutation (SNP) | VAF 97/224 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.98); catalogued as rs542255755, COSV67586734; called by muse, mutect2, varscan2
- SERPINB10 | c.234+2T>C p.X78_splice | Splice Site (SNP) | VAF 17/47 reads (36%) | catalogued as rs867852658; called by muse, mutect2, varscan2
- SERPINB8 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 55/141 reads (39%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs983037446, COSV99729419; called by muse, mutect2, varscan2
- SERPINF2 | c.1288G>A p.V430M | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.36); PolyPhen benign (0.349); catalogued as rs767217820; called by muse, mutect2
- SEZ6 | c.1818_1819del p.P607Qfs*37 | Frame Shift Del (DEL) | VAF 85/242 reads (35%) | catalogued as rs1187735034; called by pindel, varscan2
- SFMBT1 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.07); catalogued as COSV56253715; called by muse, mutect2, varscan2
- SH2B3 | c.1552C>T p.R518* | Nonsense Mutation (SNP) | VAF 160/471 reads (34%) | catalogued as rs138410505; called by muse, mutect2, varscan2
- SH3D19 | c.1165A>C p.S389R | Missense Mutation (SNP) | VAF 88/226 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.623); catalogued as rs1414299532; called by muse, mutect2, varscan2
- SIGLEC12 | c.283C>T p.L95F | Missense Mutation (SNP) | VAF 164/449 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs749559574; called by muse, mutect2, varscan2
- SIPA1L3 | c.947G>A p.R316H | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); catalogued as rs767672961, COSV55914125; called by muse, mutect2, varscan2
- SLC11A1 | c.401G>A p.R134H | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1024056581, COSV99262581; called by muse, varscan2
- SLC16A5 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 151/393 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as rs527943611, COSV61675490; called by muse, mutect2, varscan2
- SLC17A2 | c.893C>T p.T298M | Missense Mutation (SNP) | VAF 58/159 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.861); catalogued as rs780372808; called by muse, mutect2, varscan2
- SLC22A6 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as rs764704425, COSV64560393; called by muse, mutect2, varscan2
- SLC27A1 | c.1742G>A p.R581Q | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.087); catalogued as rs749948355; called by muse, mutect2, varscan2
- SLC35F4 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1171317174; called by muse, mutect2, varscan2
- SLC37A4 | c.103A>G p.M35V | Missense Mutation (SNP) | VAF 43/197 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as rs782533083; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC38A10 | c.2869C>T p.R957C | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs761780917, COSV101043559; called by muse, mutect2, varscan2
- SLC38A2 | c.647-7dup | Splice Region (INS) | VAF 10/42 reads (24%) | catalogued as rs748849616; called by mutect2, varscan2
- SLC3A2 | c.899del p.K300Rfs*31 | Frame Shift Del (DEL) | VAF 12/106 reads (11%) | catalogued as rs760089491; called by mutect2, varscan2
- SLC4A7 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 24/61 reads (39%) | catalogued as COSV55398191, COSV55402532; called by muse, mutect2, varscan2
- SLC6A11 | c.1858G>A p.G620R | Missense Mutation (SNP) | VAF 54/152 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.01); catalogued as rs367894283; called by muse, mutect2, varscan2
- SLFN11 | c.1508del p.G503Afs*15 | Frame Shift Del (DEL) | VAF 36/78 reads (46%) | catalogued as rs1006801410; called by mutect2, varscan2
- SLITRK1 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 55/484 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.069); catalogued as COSV65677758; called by muse, mutect2, varscan2
- SLITRK6 | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 295/444 reads (66%) | catalogued as rs772203918, COSV68390342; called by muse, mutect2, varscan2
- SMAP2 | c.456dup p.L153Ifs*7 | Frame Shift Ins (INS) | VAF 22/75 reads (29%) | catalogued as rs761074086; called by mutect2, varscan2
- SMARCA4 | c.3484G>A p.G1162S | Missense Mutation (SNP) | VAF 234/570 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100759311, COSV60788440, COSV60801054; called by muse, mutect2, varscan2
- SMARCA4 | c.3968G>A p.R1323H | Missense Mutation (SNP) | VAF 186/438 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs61750054; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SMARCAD1 | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 121/359 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV104415849; called by muse, mutect2, varscan2
- SMARCD2 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 57/128 reads (45%) | catalogued as rs1249857785; called by muse, mutect2, varscan2
- SMC4 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs555051191; called by muse, mutect2, varscan2
- SMC6 | c.1228del p.I410Yfs*4 | Frame Shift Del (DEL) | VAF 24/60 reads (40%) | catalogued as rs760667210; called by mutect2, varscan2
- SMG5 | c.1822G>A p.V608I | Missense Mutation (SNP) | VAF 159/269 reads (59%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs747856661; called by muse, mutect2, varscan2
- SMIM12 | c.127G>A p.V43M | Missense Mutation (SNP) | VAF 185/445 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as rs757344275; called by muse, mutect2, varscan2
- SMOC2 | c.1054G>C p.V352L (on ENST00000356284 / NM_001166412.2; = p.V363L on NM_022138.3) | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.531); catalogued as rs991950351; called by muse, mutect2
- SNX27 | c.592C>T p.R198W | Missense Mutation (SNP) | VAF 83/139 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV64325892; called by muse, mutect2, varscan2
- SOX13 | c.1010del p.P337Rfs*69 | Frame Shift Del (DEL) | VAF 52/234 reads (22%) | catalogued as rs1362904355; called by pindel, varscan2
- SP9 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 77/173 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs770414076; called by muse, mutect2, varscan2
- SPAG9 | c.1645del p.R549Gfs*28 (on ENST00000262013 / NM_001130528.3; = p.R535Gfs*28 on NM_003971.6) | Frame Shift Del (DEL) | VAF 27/64 reads (42%) | catalogued as rs371303534; called by mutect2, varscan2
- SPDL1 | c.1487A>G p.D496G | Missense Mutation (SNP) | VAF 134/290 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.295); catalogued as rs1173874840; called by muse, mutect2
- SPDYE6 | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 198/1794 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs781978914; called by muse, varscan2
- SPECC1L | c.2218C>T p.R740W | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200485910, COSV58659992; called by muse, mutect2, varscan2
- SPIB | c.64G>A p.V22I | Missense Mutation (SNP) | VAF 62/157 reads (39%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs887253633, COSV54529461; called by muse, mutect2, varscan2
- SPIRE2 | c.1211G>A p.R404Q | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.845); catalogued as rs746735318, COSV65556716; called by muse, mutect2, varscan2
- SPRED1 | c.1282C>T p.R428C | Missense Mutation (SNP) | VAF 93/211 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs941091989, COSV54436162; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPRR2G | c.68G>T p.C23F | Missense Mutation (SNP) | VAF 203/373 reads (54%) | PolyPhen possibly damaging (0.619); catalogued as COSV64203496; called by muse, mutect2, varscan2
- SPX | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 11/179 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57020762, COSV99919500; called by muse, mutect2
- SRGAP1 | c.1754G>A p.R585H | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs912990988; called by muse, varscan2
- SRMS | c.553C>T p.R185W | Missense Mutation (SNP) | VAF 129/322 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs368291555; called by muse, mutect2, varscan2
- SRRM2 | c.55G>A p.V19I | Missense Mutation (SNP) | VAF 26/320 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.939); catalogued as rs776166306, COSV100070440; called by muse, mutect2
- ST6GALNAC4 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 171/380 reads (45%) | PolyPhen probably damaging (0.998); catalogued as rs1294543745, COSV100231430; called by muse, mutect2, varscan2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 56/141 reads (40%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD5 | c.71C>T p.T24I | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV57154159; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2689G>A p.V897M | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.176); catalogued as rs771832363, COSV59134378; called by muse, mutect2, varscan2
- STPG2 | c.391G>T p.V131F | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT tolerated (0.74); PolyPhen benign (0.007); catalogued as COSV54785118; called by muse, mutect2, varscan2
- STRA6 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 90/197 reads (46%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.533); catalogued as rs772134481, COSV60588811; called by muse, varscan2
- STRADA | c.997del p.R333Gfs*42 (on ENST00000336174 / NM_001363786.1; = p.R296Gfs*58 on NM_153335.6) | Frame Shift Del (DEL) | VAF 135/368 reads (37%) | catalogued as rs762120842, COSV51992441; called by pindel, varscan2
- STXBP5L | c.1459T>C p.Y487H | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1356216062; called by muse, mutect2
- SUPT6H | c.266G>A p.R89H | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs746218200, COSV58929100; called by muse, mutect2, varscan2
- SVIL | c.5586del p.M1863Wfs*44 (on ENST00000355867 / NM_021738.3; = p.M1437Wfs*44 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 72/208 reads (35%) | catalogued as rs770033147; called by mutect2, varscan2
- SYDE1 | c.820G>A p.G274S | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1171279722, COSV54621839; called by muse, mutect2
- SYNM | c.2837G>A p.R946Q | Missense Mutation (SNP) | VAF 211/581 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs782799108; called by muse, mutect2, varscan2
- SYNPO2L | c.415G>A p.G139R | Missense Mutation (SNP) | VAF 104/271 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765646688; called by muse, mutect2, varscan2
- SYNRG | c.3700A>G p.M1234V | Missense Mutation (SNP) | VAF 39/199 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.959); catalogued as rs1003225090; called by muse, mutect2, varscan2
- SYNRG | c.3640G>A p.G1214S | Missense Mutation (SNP) | VAF 53/154 reads (34%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as rs750538973; called by muse, mutect2, varscan2
- TACC2 | c.3977T>C p.M1326T | Missense Mutation (SNP) | VAF 134/279 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs1284744082; called by muse, mutect2, varscan2
- TAF1C | c.1361del p.P454Lfs*14 | Frame Shift Del (DEL) | VAF 82/174 reads (47%) | catalogued as rs749363736; called by mutect2, varscan2
- TBC1D1 | c.928del p.I310* | Frame Shift Del (DEL) | VAF 18/65 reads (28%) | catalogued as rs760298745; called by mutect2, pindel, varscan2
- TBX10 | c.291dup p.F98Lfs*72 | Frame Shift Ins (INS) | VAF 267/738 reads (36%) | catalogued as rs748952707; called by mutect2, varscan2
- TDRD6 | c.29C>T p.P10L | Missense Mutation (SNP) | VAF 41/88 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs748354624; called by muse, mutect2, varscan2
- TEKT1 | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 54/126 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs139532367; called by muse, mutect2, varscan2
- TEKT5 | c.1073C>T p.T358M | Missense Mutation (SNP) | VAF 188/454 reads (41%) | SIFT tolerated (0.26); PolyPhen benign (0.017); catalogued as rs767939919, COSV51587659; called by muse, mutect2, varscan2
- TENM3 | c.7769C>T p.T2590M | Missense Mutation (SNP) | VAF 50/145 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV101305083; called by muse, mutect2, varscan2
- TERB1 | c.163C>T p.R55W | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1265258881; called by muse, varscan2
- TERT | c.329del p.G110Afs*18 | Frame Shift Del (DEL) | VAF 107/279 reads (38%) | catalogued as rs1554043093, CM157417, COSV99721811; called by mutect2, pindel, varscan2
- TET1 | c.319C>T p.R107* | Nonsense Mutation (SNP) | VAF 82/226 reads (36%) | catalogued as rs771320434, COSV65381864; called by muse, mutect2, varscan2
- TFIP11 | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 77/206 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.99); catalogued as rs1437137361; called by muse, mutect2, varscan2
- TG | c.7664G>A p.R2555H | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.677); catalogued as rs373473584; called by muse, mutect2, varscan2
- TGM2 | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 205/464 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.251); catalogued as rs574234671; called by muse, mutect2, varscan2
- THBD | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 249/655 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.124); catalogued as rs751318683; called by muse, mutect2, varscan2
- THOC6 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 70/181 reads (39%) | SIFT tolerated (0.84); PolyPhen benign (0.003); catalogued as rs760705881, COSV50187562; called by muse, mutect2, varscan2
- THRB | c.1289T>C p.M430T | Missense Mutation (SNP) | VAF 165/461 reads (36%) | SIFT tolerated (0.92); PolyPhen possibly damaging (0.684); catalogued as rs757196258; called by muse, mutect2, varscan2
- TLE3 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 85/251 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1227732728, COSV58172366; called by muse, mutect2, varscan2
- TMC4 | c.1405A>G p.N469D (on ENST00000617472 / NM_001145303.3; = p.N463D on NM_144686.4) | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as COSV99714155; called by muse, mutect2, varscan2
- TMCC2 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 153/503 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.98); catalogued as rs1351231482, COSV63665846; called by muse, mutect2, varscan2
- TMEM132C | c.1121G>T p.R374M | Missense Mutation (SNP) | VAF 43/87 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV59422797; called by muse, mutect2, varscan2
- TMEM234 | c.217C>A p.L73I | Missense Mutation (SNP) | VAF 46/154 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.372); catalogued as COSV59084184; called by muse, mutect2, varscan2
- TMEM8B | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 108/250 reads (43%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs749330727, COSV65075888; called by muse, mutect2, varscan2
- TMOD3 | c.282del p.I97Yfs*23 | Frame Shift Del (DEL) | VAF 23/60 reads (38%) | catalogued as rs759399045; called by mutect2, varscan2
- TMSB15A | c.80del p.N27Ifs*49 | Frame Shift Del (DEL) | VAF 42/65 reads (65%) | catalogued as rs782090690; called by mutect2, pindel, varscan2
- TMTC4 | c.1199A>G p.N400S (on ENST00000376234 / NM_001350577.2; = p.N419S on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV60891307; called by muse, mutect2, varscan2
- TNFRSF11B | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 84/326 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs529894410, COSV52070972; called by muse, mutect2, varscan2
- TNIK | c.2269C>T p.R757C | Missense Mutation (SNP) | VAF 75/186 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772569718; called by muse, mutect2, varscan2
- TNIP3 | c.230C>T p.T77M | Missense Mutation (SNP) | VAF 90/232 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.05); catalogued as COSV50248294; called by muse, mutect2, varscan2
- TOPBP1 | c.2144C>T p.A715V | Missense Mutation (SNP) | VAF 109/244 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53438176; called by muse, mutect2, varscan2
- TP53BP1 | c.4063C>T p.R1355* | Nonsense Mutation (SNP) | VAF 89/228 reads (39%) | catalogued as rs773155828, COSV55510993; called by muse, mutect2, varscan2
- TP53BP2 | c.1574A>G p.Q525R (on ENST00000343537 / NM_001031685.3; = p.Q396R on NM_005426.2) | Missense Mutation (SNP) | VAF 182/308 reads (59%) | SIFT tolerated (0.5); PolyPhen benign (0.068); catalogued as rs1270921710; called by muse, mutect2, varscan2
- TPPP2 | c.22dup p.T8Nfs*17 | Frame Shift Ins (INS) | VAF 71/183 reads (39%) | catalogued as rs746244209; called by mutect2, pindel, varscan2
- TPST2 | c.996dup p.N333Qfs*6 | Frame Shift Ins (INS) | VAF 44/141 reads (31%) | catalogued as rs756080117; called by mutect2, varscan2
- TPST2 | c.245C>T p.T82M | Missense Mutation (SNP) | VAF 84/194 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); catalogued as rs748100294; called by muse, mutect2, varscan2
- TRA2A | c.65C>T p.T22M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.026); catalogued as rs201740711, COSV51719141; called by muse, mutect2, varscan2
- TRABD | c.583G>A p.V195I | Missense Mutation (SNP) | VAF 162/399 reads (41%) | SIFT tolerated (0.59); PolyPhen benign (0.304); catalogued as rs776065922, COSV57713728; called by muse, mutect2, varscan2
- TRAPPC9 | c.3214G>A p.V1072M | Missense Mutation (SNP) | VAF 237/836 reads (28%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.973); catalogued as rs762076098, COSV101228505; called by muse, mutect2, varscan2
- TREML2 | c.8del p.P3Qfs*27 | Frame Shift Del (DEL) | VAF 57/182 reads (31%) | catalogued as COSV72439241; called by pindel, varscan2
- TRIL | c.2329G>T p.A777S | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as rs1321861614, COSV59868175; called by muse, mutect2, varscan2
- TRIM51 | c.430del p.M144Cfs*15 | Frame Shift Del (DEL) | VAF 26/72 reads (36%) | catalogued as rs763121810; called by mutect2, varscan2
- TRIM55 | c.529G>A p.A177T | Missense Mutation (SNP) | VAF 53/129 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); catalogued as rs372993762, COSV52543139; called by muse, mutect2, varscan2
- TRIP12 | c.2639del p.N880Ifs*17 | Frame Shift Del (DEL) | VAF 35/80 reads (44%) | catalogued as COSV52265421; called by mutect2, pindel, varscan2
- TRMT12 | c.594G>T p.W198C | Missense Mutation (SNP) | VAF 189/702 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60777548; called by muse, mutect2, varscan2
- TRMT6 | c.1243C>T p.R415W | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385924852; called by muse, mutect2, varscan2
- TSC1 | c.1859T>C p.V620A | Missense Mutation (SNP) | VAF 116/308 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs1392416235, COSV53765577; called by muse, mutect2, varscan2
- TSGA10IP | c.431G>A p.R144H | Missense Mutation (SNP) | VAF 99/284 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs759743147; called by muse, mutect2, varscan2
- TSHZ2 | c.2454dup p.M819Hfs*11 | Frame Shift Ins (INS) | VAF 40/136 reads (29%) | catalogued as rs1193207010; called by mutect2, varscan2
- TSPYL4 | c.551del p.K184Rfs*6 | Frame Shift Del (DEL) | VAF 102/309 reads (33%) | catalogued as rs866864072; called by mutect2, pindel, varscan2
- TSSK2 | c.825del p.K276Sfs*30 | Frame Shift Del (DEL) | VAF 97/257 reads (38%) | catalogued as rs764514103; called by mutect2, pindel, varscan2
- TTC39A | c.89G>A p.R30H | Missense Mutation (SNP) | VAF 66/208 reads (32%) | SIFT tolerated (0.08); catalogued as rs758323914; called by muse, mutect2, varscan2
- TTK | c.2560del p.R854Gfs*39 | Frame Shift Del (DEL) | VAF 26/64 reads (41%) | catalogued as rs763254614; called by mutect2, varscan2
- TTN | c.52850T>C p.I17617T (on ENST00000591111; = p.I10193T on NM_003319.4) | Missense Mutation (SNP) | VAF 90/221 reads (41%) | PolyPhen benign (0.439); catalogued as rs1360164741; called by muse, varscan2
- TUB | c.1091G>A p.R364H (on ENST00000299506 / NM_177972.3; = p.R419H on NM_003320.4) | Missense Mutation (SNP) | VAF 93/232 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1424030779, COSV55107503; called by muse, mutect2, varscan2
- TUBB6 | c.1171C>T p.R391C | Missense Mutation (SNP) | VAF 180/432 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.262); catalogued as COSV52316990; called by muse, mutect2, varscan2
- TUBD1 | c.859T>C p.Y287H | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV100360172; called by muse, mutect2, varscan2
- TVP23A | c.420del p.F140Lfs*7 | Frame Shift Del (DEL) | VAF 18/43 reads (42%) | catalogued as rs760251146; called by mutect2, varscan2
- TXLNB | c.688-1G>T p.X230_splice | Splice Site (SNP) | VAF 54/130 reads (42%) | catalogued as COSV100625011, COSV62727434; called by muse, mutect2
- TYK2 | c.1562G>A p.R521Q | Missense Mutation (SNP) | VAF 161/450 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.091); catalogued as rs546087218; called by muse, mutect2, varscan2
- UBA52 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 36/114 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV55889549; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 136/229 reads (59%) | catalogued as rs763652408; called by mutect2, varscan2
- UMOD | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 154/389 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs760112940, COSV56779513, COSV56780445; called by muse, mutect2, varscan2
- UNC13C | c.3127del p.T1043Lfs*10 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs749125502, COSV52929254; called by mutect2, varscan2
- UNCX | c.514C>T p.R172W | Missense Mutation (SNP) | VAF 68/169 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100310317, COSV60332773; called by muse, mutect2, varscan2
- URB2 | c.4222C>T p.R1408W | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1318884599; called by muse, mutect2, varscan2
- USO1 | c.1351A>G p.N451D | Missense Mutation (SNP) | VAF 86/191 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.642); catalogued as rs745908392; called by muse, mutect2, varscan2
- VASH2 | c.413C>T p.P138L (on ENST00000517399 / NM_001301056.2; = p.P73L on NM_001136474.3) | Missense Mutation (SNP) | VAF 25/168 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780891441, COSV55117040; called by muse, mutect2, varscan2
- VASN | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 116/309 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs764619660, COSV52028265; called by muse, mutect2, varscan2
- VGLL3 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs766327450; called by muse, varscan2
- VPS13A | c.5492C>T p.T1831I | Missense Mutation (SNP) | VAF 49/145 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62425300; called by muse, mutect2, varscan2
- VPS33A | c.246del p.F82Lfs*6 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | catalogued as rs756221452; called by mutect2, varscan2
- VPS35 | c.975del p.F325Lfs*11 | Frame Shift Del (DEL) | VAF 50/154 reads (32%) | catalogued as COSV54478426; called by pindel, varscan2
- VPS37B | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs760564451; called by muse, mutect2, varscan2
- VRTN | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 76/192 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs760708028; called by muse, mutect2, varscan2
- VTI1B | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1311189346, COSV53619778; called by muse, mutect2, varscan2
- VWA1 | c.633C>T p.D211= | Splice Region (SNP) | VAF 122/291 reads (42%) | catalogued as COSV58599851, COSV58600455; called by muse, mutect2, varscan2
- WAPL | c.3484T>A p.F1162I | Missense Mutation (SNP) | VAF 27/66 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV53932999; called by muse, mutect2, varscan2
- WDR17 | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54585157; called by muse, mutect2, varscan2
- WDR49 | c.1821del p.K607Nfs*9 (on ENST00000308378 / NM_001366158.1; = p.K948Nfs*9 on NM_001348951.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as rs755423544; called by mutect2, varscan2
- WDR49 | c.211T>G p.F71V (on ENST00000308378 / NM_001366158.1; = p.F412V on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.134); catalogued as COSV57710169; called by muse, mutect2, varscan2
- WDR86 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 163/403 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs774752569, COSV57837824; called by muse, mutect2, varscan2
- WDR91 | c.995G>A p.R332H | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.968); catalogued as rs758348350; called by muse, mutect2, varscan2
- WNK2 | c.5030C>T p.T1677M (on ENST00000297954 / NM_001282394.1; = p.T1640M on NM_006648.3) | Missense Mutation (SNP) | VAF 63/203 reads (31%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as rs761334827; called by muse, mutect2, varscan2
- WNT1 | c.506del p.G169Afs*30 | Frame Shift Del (DEL) | VAF 65/343 reads (19%) | catalogued as COSV53295493; called by mutect2, pindel, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 143/433 reads (33%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WNT4 | c.95C>T p.S32L | Missense Mutation (SNP) | VAF 243/617 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as rs1434900917; called by muse, mutect2, varscan2
- WWOX | c.263C>T p.P88L | Missense Mutation (SNP) | VAF 76/172 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200371768; called by muse, varscan2
- WWOX | c.500G>A p.R167H | Missense Mutation (SNP) | VAF 79/231 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.066); catalogued as rs377356629; called by muse, mutect2, varscan2
- XK | c.1222A>G p.I408V | Missense Mutation (SNP) | VAF 14/204 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs998525572; called by muse, mutect2
- YBX3 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs146058214, COSV54387121; called by muse, mutect2, varscan2
- ZBED1 | c.476G>A p.R159Q | Missense Mutation (SNP) | VAF 185/420 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.665); catalogued as rs758632919; called by muse, mutect2, varscan2
- ZBTB40 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 162/387 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs762076099, COSV65146600; called by muse, mutect2, varscan2
- ZBTB46 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 95/251 reads (38%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); catalogued as rs747229921, COSV55507603; called by muse, mutect2, varscan2
- ZDHHC3 | c.221T>C p.V74A | Missense Mutation (SNP) | VAF 86/542 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs1267867453; called by muse, mutect2, varscan2
- ZFHX4 | c.5876T>G p.L1959R | Missense Mutation (SNP) | VAF 84/242 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51471130; called by muse, mutect2, varscan2
- ZFP64 | c.1378G>A p.V460I | Missense Mutation (SNP) | VAF 46/111 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs748012399; called by muse, mutect2, varscan2
- ZFP82 | c.544C>T p.R182C | Missense Mutation (SNP) | VAF 102/256 reads (40%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.945); catalogued as rs778648836, COSV67564701; called by muse, mutect2, varscan2
- ZKSCAN5 | c.1304G>A p.C435Y | Missense Mutation (SNP) | VAF 52/149 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201037728; called by muse, mutect2, varscan2
- ZMIZ2 | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 195/514 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.097); catalogued as rs766142134, COSV54809850; called by muse, mutect2, varscan2
- ZMYM5 | c.778C>T p.R260* | Nonsense Mutation (SNP) | VAF 55/376 reads (15%) | catalogued as rs781463793, COSV61989315, COSV61989497; called by muse, mutect2, varscan2
- ZNF141 | c.1336A>G p.T446A | Missense Mutation (SNP) | VAF 69/190 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.229); catalogued as COSV53660147; called by muse, mutect2, varscan2
- ZNF142 | c.3755del p.G1252Dfs*20 (on ENST00000411696 / NM_001379660.1; = p.G1052Dfs*20 on NM_001105537.4 and 5 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 169/299 reads (57%) | catalogued as rs751589999; called by mutect2, varscan2
- ZNF142 | c.1541G>A p.R514Q (on ENST00000411696 / NM_001379660.1; = p.R314Q on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 256/623 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.122); catalogued as rs1448022087; called by muse, mutect2, varscan2
- ZNF275 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 133/172 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782256821, COSV64703971; called by muse, mutect2, varscan2
- ZNF318 | c.1769C>T p.A590V | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as rs140875594, COSV58938893; called by muse, mutect2, varscan2
- ZNF354C | c.52G>A p.A18T | Missense Mutation (SNP) | VAF 6/115 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV59608454; called by muse, mutect2
- ZNF446 | c.1116G>T p.E372D | Missense Mutation (SNP) | VAF 229/470 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.109); catalogued as COSV59991833; called by muse, varscan2
- ZNF468 | c.696del p.K232Nfs*4 | Frame Shift Del (DEL) | VAF 94/263 reads (36%) | catalogued as COSV54697628; called by mutect2, pindel, varscan2
- ZNF516 | c.982G>A p.V328I | Missense Mutation (SNP) | VAF 184/402 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV104437613; called by muse, mutect2, varscan2
- ZNF607 | c.1144C>T p.R382* | Nonsense Mutation (SNP) | VAF 87/236 reads (37%) | catalogued as rs562952448, COSV100777901; called by muse, mutect2, varscan2
- ZNF608 | c.3976C>T p.R1326W | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs374342163; called by muse, mutect2, varscan2
- ZNF687 | c.2950_2952del p.K984del | In Frame Del (DEL) | VAF 48/176 reads (27%) | catalogued as rs774734408; called by pindel, varscan2
- ZNF703 | c.58A>G p.S20G | Missense Mutation (SNP) | VAF 59/165 reads (36%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs1563298371; called by muse, mutect2, varscan2
- ZNF704 | c.1195A>G p.T399A | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59924762; called by muse, varscan2
- ZNF786 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 128/307 reads (42%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV100303071; called by muse, mutect2, varscan2
- ZNF839 | c.563C>T p.S188L (on ENST00000558850 / NM_001267827.1; = p.S304L on NM_018335.5) | Missense Mutation (SNP) | VAF 99/249 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs368921112; called by muse, mutect2, varscan2
- ZNF852 | c.1619G>A p.S540N | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.012); catalogued as rs745331003; called by muse, mutect2, varscan2
- ZNF880 | c.1611del p.K537Nfs*60 | Frame Shift Del (DEL) | VAF 69/191 reads (36%) | catalogued as rs759348115; called by mutect2, pindel, varscan2
- ZP2 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 41/103 reads (40%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs779162964, COSV54811927; called by muse, mutect2, varscan2
- AARS1 | c.2400G>T p.E800D | Missense Mutation (SNP) | VAF 216/554 reads (39%) | SIFT tolerated (0.46); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABCB9 | c.1766C>A p.P589H (on ENST00000280560 / NM_019625.4; = p.P546H on NM_019624.3) | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCC3 | c.1254G>T p.Q418H | Missense Mutation (SNP) | VAF 200/488 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABHD16B | c.149T>C p.L50P | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.274); called by muse, mutect2, varscan2
- AC100868.1 | c.1268-1G>A p.X423_splice | Splice Site (SNP) | VAF 57/237 reads (24%) | called by muse, mutect2, varscan2
- ACTL7B | c.658A>C p.S220R | Missense Mutation (SNP) | VAF 126/284 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAM22 | c.652C>T p.P218S | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADAMTS12 | c.3524T>C p.V1175A | Missense Mutation (SNP) | VAF 61/150 reads (41%) | SIFT tolerated (0.6); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ADAMTS12 | c.2066A>T p.D689V | Missense Mutation (SNP) | VAF 44/105 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS5 | c.90dup p.A31Sfs*109 | Frame Shift Ins (INS) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- ADAMTS9 | c.5176del p.T1726Pfs*17 | Frame Shift Del (DEL) | VAF 31/85 reads (36%) | called by mutect2, pindel, varscan2
- ADAMTSL2 | c.1018del p.Q340Sfs*21 | Frame Shift Del (DEL) | VAF 181/478 reads (38%) | called by mutect2, pindel, varscan2
- AGL | c.4144A>G p.T1382A | Missense Mutation (SNP) | VAF 83/224 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- AGXT2 | c.1309A>G p.M437V | Missense Mutation (SNP) | VAF 124/336 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- AKAP12 | c.1002del p.V335* | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, varscan2
- AKAP7 | c.291+2T>C p.X97_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | called by muse, mutect2, varscan2
- ALLC | c.10G>T p.A4S | Missense Mutation (SNP) | VAF 10/198 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.78); called by muse, mutect2
- ALS2 | c.4147del p.L1383Wfs*14 | Frame Shift Del (DEL) | VAF 60/202 reads (30%) | called by mutect2, pindel, varscan2
- AMIGO1 | c.873C>A p.D291E | Missense Mutation (SNP) | VAF 164/458 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANKRD11 | c.3417G>T p.E1139D | Missense Mutation (SNP) | VAF 209/494 reads (42%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD30A | c.896T>C p.V299A (on ENST00000611781; = p.V243A on NM_052997.2) | Missense Mutation (SNP) | VAF 76/205 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- ANKRD35 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AP4M1 | c.566del p.L189Wfs*10 | Frame Shift Del (DEL) | VAF 177/538 reads (33%) | called by mutect2, pindel, varscan2
- APEH | c.607-1G>T p.X203_splice | Splice Site (SNP) | VAF 85/238 reads (36%) | called by muse, mutect2, varscan2
- APOBEC1 | c.207dup p.F70Ifs*32 | Frame Shift Ins (INS) | VAF 91/200 reads (46%) | called by mutect2, varscan2
- APOBEC3G | c.571del p.E191Rfs*45 | Frame Shift Del (DEL) | VAF 38/134 reads (28%) | called by mutect2, pindel, varscan2
- ARHGEF26 | c.1567G>T p.A523S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.73); PolyPhen benign (0.007); called by muse, varscan2
- ARVCF | c.2811del p.S940Afs*11 | Frame Shift Del (DEL) | VAF 82/240 reads (34%) | called by pindel, varscan2
- ASTN1 | c.2190T>A p.F730L | Missense Mutation (SNP) | VAF 94/290 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ASXL2 | c.383del p.K128Rfs*39 | Frame Shift Del (DEL) | VAF 54/190 reads (28%) | called by pindel, varscan2
- ATP12A | c.2798G>T p.G933V | Missense Mutation (SNP) | VAF 210/302 reads (70%) | SIFT deleterious (0.02); PolyPhen benign (0.192); called by muse, varscan2
- ATP2B4 | c.143A>G p.Y48C | Missense Mutation (SNP) | VAF 65/115 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- ATRIP | c.1033del p.L345Cfs*31 | Frame Shift Del (DEL) | VAF 28/79 reads (35%) | called by mutect2, pindel, varscan2
- ATXN2L | c.2408A>G p.Q803R | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- AVPR1A | c.892A>G p.T298A | Missense Mutation (SNP) | VAF 136/349 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- AZU1 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 82/234 reads (35%) | SIFT tolerated (0.26); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- B3GALT2 | c.496G>A p.A166T | Missense Mutation (SNP) | VAF 98/342 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.95); called by mutect2, varscan2
- B3GLCT | c.238del p.S80Afs*3 | Frame Shift Del (DEL) | VAF 151/224 reads (67%) | called by mutect2, varscan2
- BAHCC1 | c.2502del p.H835Tfs*139 | Frame Shift Del (DEL) | VAF 81/209 reads (39%) | called by mutect2, pindel, varscan2
- BBS7 | c.1918A>G p.N640D | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.89); PolyPhen benign (0); called by muse, mutect2
- BCAN | c.2525A>G p.Y842C | Missense Mutation (SNP) | VAF 20/358 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BCL6 | c.7T>G p.S3A | Missense Mutation (SNP) | VAF 17/494 reads (3%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2
- BEST2 | c.863T>C p.L288P | Missense Mutation (SNP) | VAF 85/202 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- BICRAL | c.2866T>C p.S956P | Missense Mutation (SNP) | VAF 158/361 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.001); called by muse, varscan2
- BIRC3 | c.984G>T p.Q328H | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- BLMH | c.482C>A p.P161H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- BPTF | c.3811T>C p.S1271P | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- BUB1 | c.2661del p.V888* | Frame Shift Del (DEL) | VAF 40/99 reads (40%) | called by mutect2, pindel, varscan2
- BUB1B | c.869C>A p.P290H | Missense Mutation (SNP) | VAF 130/328 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- C10orf71 | c.1252del p.Q418Rfs*30 | Frame Shift Del (DEL) | VAF 59/188 reads (31%) | called by mutect2, pindel, varscan2
- C14orf93 | c.1197+2T>A p.X399_splice | Splice Site (SNP) | VAF 46/119 reads (39%) | called by muse, mutect2, varscan2
- C1QB | c.652del p.E218Rfs*73 | Frame Shift Del (DEL) | VAF 109/293 reads (37%) | called by mutect2, pindel, varscan2
- C1orf56 | c.98T>C p.M33T | Missense Mutation (SNP) | VAF 100/340 reads (29%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); called by muse, mutect2, varscan2
- C3 | c.4808T>C p.L1603P | Missense Mutation (SNP) | VAF 444/1057 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- C3orf20 | c.1463T>G p.L488R | Missense Mutation (SNP) | VAF 68/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- C3orf49 | c.861del p.G288Dfs*34 | Frame Shift Del (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
- C5orf15 | c.625del p.C209Afs*38 | Frame Shift Del (DEL) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1A | c.6687dup p.D2230Rfs*40 (on ENST00000614285; = p.D2230Rfs*41 on NM_000068.4) | Frame Shift Ins (INS) | VAF 90/256 reads (35%) | called by pindel, varscan2
- CACNA1A | c.4955A>G p.E1652G | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
1,163 further variants in this file (556 protein-altering or splice-affecting, 361 silent, 246 other) are not listed here.
